Somatic mutation profile of tumor specimen TCGA-05-4398-01A (aliquot TCGA-05-4398-01A-01D-1265-08) from TCGA case TCGA-05-4398, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 47.8 years (17,471 days).
Specimen TCGA-05-4398-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d2d325a-9f06-4f14-9ed1-db7e3f203117.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-05-4398-10A (Blood Derived Normal), aliquot TCGA-05-4398-10A-01D-1265-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a6d9946-9ac1-4924-9d24-f8a7e0fbcf72

The open-access MAF lists 761 somatic variants for this specimen: 567 protein-altering or splice-affecting, 178 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 484, Silent 178, Nonsense Mutation 33, Splice Site 25, Frame Shift Del 15, Intron 7, RNA 6, Frame Shift Ins 6, Splice Region 4, 3'Flank 1, 5'Flank 1, 3'UTR 1.

Variants (750 of 761; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPS1 | c.2407C>A p.R803S | Missense Mutation (SNP) | VAF 33/253 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201716417, CM098027, CM114352, CM114353, COSV51810496, COSV51817776; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GRIN2B | c.99dup p.S34Qfs*25 | Frame Shift Ins (INS) | VAF 11/85 reads (13%) | catalogued as rs398122823; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- TP53 | c.314G>A p.G105D | Missense Mutation (SNP) | VAF 27/83 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs587781504, COSV52708806, COSV52766179, COSV52793434; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.14129A>C p.E4710A | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.087); catalogued as COSV68949135; called by muse, mutect2
- ABCA6 | c.1682G>T p.C561F | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52641893; called by muse, mutect2, varscan2
- ABCB1 | c.696G>T p.W232C | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.985); catalogued as COSV55957404; called by muse, mutect2
- ABHD2 | c.1057C>G p.L353V | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.349); catalogued as COSV61775293; called by muse, mutect2, varscan2
- ABITRAM | c.313G>C p.D105H | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100336378; called by muse, mutect2, varscan2
- ABTB2 | c.1242A>G p.E414= | Splice Region (SNP) | VAF 17/83 reads (20%) | catalogued as COSV54392445; called by muse, mutect2, varscan2
- AC136428.1 | c.342C>A p.Y114* | Nonsense Mutation (SNP) | VAF 22/265 reads (8%) | catalogued as COSV101434946; called by muse, mutect2
- ACTN2 | c.139T>A p.W47R | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63976948; called by muse, mutect2, varscan2
- ACTN2 | c.540G>T p.W180C | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63976952; called by muse, mutect2
- ADAM2 | c.1240T>A p.C414S | Missense Mutation (SNP) | VAF 51/230 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55865393; called by muse, mutect2, varscan2
- ADAM28 | c.1481G>T p.G494V | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs892008783, COSV56103002, COSV56103665; called by muse, mutect2, varscan2
- ADAMTS12 | c.4543G>T p.D1515Y | Missense Mutation (SNP) | VAF 10/125 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV61271017; called by muse, mutect2
- ADAMTS5 | c.2114G>T p.R705I | Missense Mutation (SNP) | VAF 19/241 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53182101; called by muse, mutect2
- ADAR | c.1602-1G>T p.X534_splice | Splice Site (SNP) | VAF 22/201 reads (11%) | catalogued as rs1317389715, COSV52713846, COSV99426716; called by muse, mutect2
- ADCY8 | c.3424G>T p.D1142Y | Missense Mutation (SNP) | VAF 16/262 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV53918007; called by muse, mutect2
- ADGRA3 | c.2993G>T p.G998V | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.933); catalogued as COSV51560355, COSV51566097; called by muse, mutect2, varscan2
- ADGRE3 | c.1802T>A p.L601H | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53732939; called by muse, mutect2, varscan2
- ADGRL2 | c.977C>A p.S326* | Nonsense Mutation (SNP) | VAF 14/122 reads (11%) | catalogued as COSV54678145; called by muse, mutect2
- AFF2 | c.1096C>A p.H366N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); catalogued as COSV53998825; called by muse, mutect2, varscan2
- AHNAK2 | c.1684A>G p.R562G | Missense Mutation (SNP) | VAF 35/456 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV60922760; called by muse, mutect2
- AJAP1 | c.1043C>A p.T348K | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65452314; called by muse, mutect2, varscan2
- AK5 | c.61-1G>T p.X21_splice | Splice Site (SNP) | VAF 14/79 reads (18%) | catalogued as COSV100481538, COSV58356521; called by muse, mutect2, varscan2
- AKAP9 | c.3486G>T p.Q1162H | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.061); catalogued as COSV62350586, COSV62352748; called by muse, mutect2, varscan2
- AKAP9 | c.4406A>G p.E1469G | Missense Mutation (SNP) | VAF 13/202 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV62352768; called by muse, mutect2
- AL645922.1 | c.2491A>T p.S831C | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54961713; called by muse, mutect2, varscan2
- ALPK1 | c.2907C>G p.I969M | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.388); catalogued as COSV51587785, COSV51588640; called by muse, mutect2, varscan2
- ALPK3 | c.631G>T p.D211Y | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as COSV51936683; called by muse, mutect2
- ANAPC2 | c.1487G>T p.R496L | Missense Mutation (SNP) | VAF 66/115 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV100118928, COSV60571651; called by muse, mutect2, varscan2
- ANAPC2 | c.1486C>T p.R496W | Missense Mutation (SNP) | VAF 66/114 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs779075661, COSV100118930; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.5686G>T p.V1896L | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated, low confidence (0.34); PolyPhen probably damaging (0.956); catalogued as COSV51853632; called by muse, mutect2, varscan2
- ANKRD35 | c.1145C>T p.T382I | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1553739426, COSV62911054; called by muse, mutect2, varscan2
- ANO4 | c.1214C>A p.P405Q (on ENST00000392977 / NM_001286615.2; = p.P370Q on NM_178826.4) | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.425); catalogued as COSV54605306; called by muse, mutect2, varscan2
- AOAH | c.1341G>C p.L447F | Missense Mutation (SNP) | VAF 39/254 reads (15%) | SIFT tolerated (0.75); PolyPhen benign (0.011); catalogued as COSV51746308; called by muse, mutect2, varscan2
- AP002512.3 | c.835C>A p.H279N | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV99687801; called by muse, mutect2, varscan2
- APP | c.1177A>G p.K393E | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV61001659; called by muse, mutect2
- AQR | c.3202C>A p.L1068M | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50042509; called by muse, mutect2, varscan2
- ARG1 | c.47C>G p.S16* | Nonsense Mutation (SNP) | VAF 6/79 reads (8%) | catalogued as COSV99256005; called by muse, mutect2
- ARHGAP31 | c.4057C>G p.P1353A | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51796382; called by muse, mutect2
- ARHGAP9 | c.1285G>T p.A429S | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV99953761; called by muse, mutect2, varscan2
- ARHGEF2 | c.1142A>T p.Q381L (on ENST00000361247 / NM_001162383.2; = p.Q353L on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV58113944; called by muse, mutect2, varscan2
- ARHGEF6 | c.564C>A p.Y188* | Nonsense Mutation (SNP) | VAF 56/171 reads (33%) | catalogued as COSV51688508, COSV51693828; called by muse, mutect2, varscan2
- ASAP1 | c.1315A>G p.K439E | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV63051968; called by muse, mutect2
- ASB17 | c.159A>T p.K53N | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as COSV52412516; called by muse, mutect2, varscan2
- ASXL3 | c.4409C>A p.P1470Q | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52456427, COSV52473229; called by muse, mutect2, varscan2
- ATG2A | c.4841G>T p.G1614V | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV65967420; called by muse, mutect2
- ATG4B | c.812G>T p.G271V | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV100728590; called by muse, mutect2, varscan2
- ATP10B | c.3353A>G p.Y1118C | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV59159128; called by muse, mutect2
- ATP2B4 | c.3084G>T p.Q1028H | Missense Mutation (SNP) | VAF 114/272 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); catalogued as COSV58181215; called by muse, mutect2
- ATP8A2 | c.3208C>T p.H1070Y | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV54965511; called by muse, mutect2, varscan2
- ATR | c.3945+1G>T p.X1315_splice | Splice Site (SNP) | VAF 13/45 reads (29%) | catalogued as COSV63389019; called by muse, varscan2
- B3GAT2 | c.802C>T p.Q268* | Nonsense Mutation (SNP) | VAF 10/91 reads (11%) | catalogued as COSV57642389; called by muse, mutect2, varscan2
- BAALC | c.311C>A p.T104K (on ENST00000297574 / NM_001364874.1; = p.T69K on NM_024812.3) | Missense Mutation (SNP) | VAF 43/239 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV52563604; called by muse, mutect2, varscan2
- BBS9 | c.1297G>A p.G433R | Missense Mutation (SNP) | VAF 73/286 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.283); catalogued as COSV54177945; called by muse, mutect2, varscan2
- BCAN | c.727G>T p.D243Y | Missense Mutation (SNP) | VAF 114/277 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV61258199; called by muse, mutect2, varscan2
- BEND2 | c.1781C>T p.T594I | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.17); catalogued as COSV66215354; called by muse, mutect2, varscan2
- BEST3 | c.1189C>T p.R397W | Missense Mutation (SNP) | VAF 91/177 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs924045625, COSV58300072; called by muse, mutect2, varscan2
- BICC1 | c.2597G>T p.G866V | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.617); catalogued as COSV54062961, COSV54065235; called by muse, mutect2
- BNC2 | c.3179G>A p.R1060K | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.931); catalogued as COSV66167038, COSV66171021; called by muse, varscan2
- BPI | c.200A>G p.D67G (on ENST00000262865; = p.D63G on NM_001725.3) | Missense Mutation (SNP) | VAF 17/178 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as rs572225651, COSV53407049; called by muse, mutect2, varscan2
- BPIFC | c.594G>T p.M198I | Missense Mutation (SNP) | VAF 16/269 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV55914096; called by muse, mutect2
- BVES | c.108C>G p.N36K | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.079); catalogued as COSV58948968; called by muse, varscan2
- C11orf87 | c.203T>C p.V68A | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as COSV100535690; called by muse, mutect2, varscan2
- C2CD2L | c.1072A>T p.S358C | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.871); catalogued as COSV60884430; called by muse, mutect2
- C8A | c.655-1G>T p.X219_splice | Splice Site (SNP) | VAF 19/86 reads (22%) | catalogued as COSV63485622; called by muse, mutect2, varscan2
- C8B | c.496A>C p.M166L | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as COSV64778632; called by muse, mutect2, varscan2
- CA13 | c.245G>T p.G82V | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58798602; called by muse, mutect2
- CALCR | c.587G>C p.R196T (on ENST00000649521 / NM_001164737.2; = p.R180T on NM_001742.4) | Missense Mutation (SNP) | VAF 29/258 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64010260; called by muse, mutect2, varscan2
- CALD1 | c.320G>T p.R107L | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62649429, COSV62650905; called by muse, mutect2, varscan2
- CASKIN2 | c.178G>T p.G60C | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58692022; called by muse, mutect2, varscan2
- CC2D1A | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 11/24 reads (46%) | catalogued as COSV58784962; called by muse, mutect2, varscan2
- CCDC28A | c.186G>T p.Q62H | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as rs1210234219, COSV60425506; called by muse, mutect2, varscan2
- CCR5 | c.781del p.Q261Rfs*6 | Frame Shift Del (DEL) | VAF 46/433 reads (11%) | catalogued as COSV52750899; called by mutect2, pindel, varscan2
- CD163 | c.134G>T p.G45V | Missense Mutation (SNP) | VAF 21/192 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as COSV100775724; called by muse, mutect2, varscan2
- CD163 | c.134-1G>T p.X45_splice | Splice Site (SNP) | VAF 21/194 reads (11%) | catalogued as COSV100775725; called by muse, mutect2, varscan2
- CD163L1 | c.139G>C p.E47Q | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.075); catalogued as COSV58020744; called by muse, mutect2, varscan2
- CD22 | c.724C>A p.P242T | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50059783; called by muse, mutect2, varscan2
- CD33 | c.610C>T p.Q204* | Nonsense Mutation (SNP) | VAF 17/70 reads (24%) | catalogued as COSV51802155; called by muse, mutect2, varscan2
- CD84 | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 24/378 reads (6%) | catalogued as COSV100245840, COSV60867252; called by muse, mutect2
- CD84 | c.303G>T p.M101I | Missense Mutation (SNP) | VAF 24/381 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100245844, COSV60870090; called by muse, mutect2
- CDH10 | c.520G>C p.V174L | Missense Mutation (SNP) | VAF 27/194 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV52589325; called by muse, mutect2, varscan2
- CDH17 | c.1558G>C p.D520H | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50325454; called by muse, mutect2
- CDH17 | c.172G>C p.V58L | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV50333823; called by muse, mutect2, varscan2
- CDH23 | c.691G>T p.D231Y | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54944051; called by muse, mutect2, varscan2
- CEBPZ | c.2972G>C p.G991A | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.97); catalogued as COSV52207473; called by muse, mutect2, varscan2
- CELA2A | c.392T>A p.V131D | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62747848; called by muse, varscan2
- CENPC | c.1859G>T p.S620I | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as COSV99893614; called by muse, mutect2, varscan2
- CEP128 | c.2403G>C p.E801D | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.074); catalogued as COSV55384440; called by muse, mutect2, varscan2
- CHAT | c.1696C>A p.R566S | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM158440, COSV60329240; called by muse, mutect2, varscan2
- CHRNB2 | c.812C>A p.S271* | Nonsense Mutation (SNP) | VAF 32/238 reads (13%) | catalogued as COSV63807857; called by muse, mutect2, varscan2
- CILP2 | c.2527G>A p.G843R | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as COSV52275383, COSV52277888; called by muse, mutect2, varscan2
- CIP2A | c.1831A>C p.K611Q | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.044); catalogued as COSV55420143; called by muse, mutect2, varscan2
- CLCNKA | c.391G>C p.A131P | Missense Mutation (SNP) | VAF 69/345 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.529); catalogued as COSV58892968; called by muse, mutect2, varscan2
- CLEC4A | c.533G>T p.W178L | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV57562385; called by muse, mutect2, varscan2
- CLTC | c.745G>A p.D249N | Missense Mutation (SNP) | VAF 32/227 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV52250145, COSV99064447; called by muse, mutect2, varscan2
- CNBD1 | c.1157G>T p.R386I | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as rs774426451, COSV73074095; called by mutect2, varscan2
- CNGA1 | c.658C>G p.L220V | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as rs752871155, COSV62055650; called by muse, mutect2
- CNTN2 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.915); catalogued as COSV59351659; called by muse, mutect2, varscan2
- CNTN3 | c.197G>T p.G66V | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55178860; called by muse, mutect2, varscan2
- CNTN4 | c.2059C>A p.R687S | Missense Mutation (SNP) | VAF 36/317 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV61876875, COSV61878084; called by muse, mutect2, varscan2
- CNTN5 | c.568C>T p.Q190* | Nonsense Mutation (SNP) | VAF 20/164 reads (12%) | catalogued as COSV54335019; called by muse, mutect2, varscan2
- CNTN5 | c.2284C>G p.P762A | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV54335040; called by muse, mutect2, varscan2
- CNTNAP2 | c.1609G>C p.A537P | Missense Mutation (SNP) | VAF 25/228 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.222); catalogued as COSV62159605, COSV62222788, COSV62222789; called by muse, mutect2, varscan2
- CNTNAP2 | c.3131C>T p.P1044L | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.036); catalogued as rs369724886, COSV62260830; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL14A1 | c.572G>T p.G191V | Missense Mutation (SNP) | VAF 77/273 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.691); catalogued as COSV52861938; called by muse, mutect2, varscan2
- COL28A1 | c.2224G>T p.G742C | Missense Mutation (SNP) | VAF 36/282 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV68083499; called by muse, mutect2, varscan2
- COL3A1 | c.2995G>T p.G999C | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM000352, CM111233, COSV58593369; called by muse, mutect2, varscan2
- COL4A2 | c.480G>T p.G160= | Splice Region (SNP) | VAF 19/59 reads (32%) | catalogued as COSV64631200; called by muse, mutect2, varscan2
- COX5B | c.217A>T p.T73S | Missense Mutation (SNP) | VAF 25/232 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.338); catalogued as COSV51480982; called by muse, mutect2, varscan2
- CPA6 | c.984G>T p.Q328H | Missense Mutation (SNP) | VAF 14/203 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52727779; called by muse, mutect2
- CPED1 | c.1856A>T p.K619M | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV60007738; called by muse, mutect2, varscan2
- CPED1 | c.2102C>A p.P701H | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV60007747; called by muse, mutect2, varscan2
- CR1L | c.1017C>G p.S339R | Missense Mutation (SNP) | VAF 37/316 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.364); catalogued as COSV54327415, COSV54329047; called by muse, mutect2, varscan2
- CSMD3 | c.5534G>T p.G1845V (on ENST00000297405 / NM_001363185.1; = p.G1741V on NM_052900.3) | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV52252122; called by muse, mutect2, varscan2
- CTNND2 | c.1894C>A p.L632M | Missense Mutation (SNP) | VAF 123/252 reads (49%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.999); catalogued as COSV58908115; called by muse, mutect2, varscan2
- CTNND2 | c.1669C>A p.Q557K | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.829); catalogued as COSV58890592, COSV58907203, COSV58908119; called by muse, mutect2
- CX3CL1 | c.175G>T p.G59C | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV50055714; called by muse, mutect2, varscan2
- CYLC2 | c.94C>T p.H32Y | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.391); catalogued as COSV66338645; called by muse, mutect2, varscan2
- CYP11B2 | c.910A>T p.I304F | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100010754, COSV100010820; called by muse, mutect2, varscan2
- CYP17A1 | c.753+2T>C p.X251_splice | Splice Site (SNP) | VAF 11/35 reads (31%) | catalogued as COSV64005038; called by muse, mutect2, varscan2
- CYP20A1 | c.432+1G>C p.X144_splice | Splice Site (SNP) | VAF 6/105 reads (6%) | catalogued as COSV61909971; called by muse, mutect2
- CYP2A6 | c.1324G>C p.E442Q | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV56536285; called by muse, varscan2
- CYP4Z1 | c.1349+2T>A p.X450_splice | Splice Site (SNP) | VAF 5/38 reads (13%) | catalogued as COSV61965959; called by muse, mutect2, varscan2
- DDX46 | c.1570A>T p.T524S | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); catalogued as COSV62800215; called by muse, mutect2, varscan2
- DHDDS | c.604A>T p.I202F | Missense Mutation (SNP) | VAF 47/205 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV52577655; called by muse, mutect2, varscan2
- DKK1 | c.139C>A p.P47T | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); catalogued as COSV64760578, COSV99059492; called by muse, mutect2, varscan2
- DMD | c.1206G>T p.L402F | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as COSV55878721, COSV55878738; called by muse, mutect2, varscan2
- DMXL1 | c.8198del p.G2733Afs*6 | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | catalogued as COSV60718428; called by mutect2, pindel, varscan2
- DNAH3 | c.4525C>G p.L1509V | Missense Mutation (SNP) | VAF 61/169 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.04); catalogued as COSV54537195; called by muse, mutect2, varscan2
- DNAH6 | c.1916A>T p.Q639L | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as COSV52873065, COSV52882493; called by muse, mutect2
- DNAH9 | c.1434G>T p.Q478H | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs1365837136, COSV52363488; called by muse, mutect2
- DNAH9 | c.6538C>A p.L2180I | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.458); catalogued as COSV52363501; called by muse, mutect2, varscan2
- DNAJC5B | c.272C>A p.A91D | Missense Mutation (SNP) | VAF 40/191 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV99395477; called by muse, mutect2, varscan2
- DOCK4 | c.182A>T p.Y61F | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.491); catalogued as COSV70323856; called by muse, mutect2, varscan2
- DOCK7 | c.3974G>T p.S1325I (on ENST00000635253 / NM_001367561.1; = p.S1294I on NM_033407.3) | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as COSV52014668; called by muse, mutect2
- DPP3 | c.2107C>T p.R703C | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201013550, COSV59150317; called by muse, mutect2, varscan2
- DRD2 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748462272, COSV60754096; called by muse, mutect2, varscan2
- DYNC2I1 | c.2155G>C p.G719R | Missense Mutation (SNP) | VAF 72/225 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101337617, COSV68106664, COSV68108062; called by muse, mutect2, varscan2
- DYNC2I1 | c.2156G>T p.G719V | Missense Mutation (SNP) | VAF 72/228 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV101337618; called by muse, mutect2, varscan2
- EBF1 | c.289A>T p.K97* | Nonsense Mutation (SNP) | VAF 9/27 reads (33%) | catalogued as COSV58187505; called by muse, mutect2, varscan2
- EFHB | c.431G>T p.R144I | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.505); catalogued as COSV55550983; called by muse, mutect2, varscan2
- EHD3 | c.501G>T p.R167= | Splice Region (SNP) | VAF 21/53 reads (40%) | catalogued as COSV59030243, COSV59032055; called by muse, mutect2, varscan2
- EIF1B | c.107A>T p.Q36L | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.222); catalogued as COSV51762731; called by muse, mutect2, varscan2
- EIPR1 | c.148G>T p.D50Y | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV66131524; called by muse, mutect2, varscan2
- ENPP2 | c.419G>A p.G140E | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV50025142; called by muse, mutect2
- ENPP7 | c.237C>A p.H79Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV60387279; called by muse, mutect2
- EPHA8 | c.866T>G p.L289R | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs920922969, COSV51279727; called by muse, mutect2, varscan2
- ERICH3 | c.3960G>T p.M1320I | Missense Mutation (SNP) | VAF 49/186 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100444941, COSV58612964; called by muse, varscan2
- EVC2 | c.2424G>C p.Q808H | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs541956407, COSV60398310; called by mutect2, varscan2
- EYA4 | c.1426G>T p.G476C (on ENST00000531901 / NM_001301013.1; = p.G470C on NM_004100.5) | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100765893, COSV62057320; called by muse, mutect2, varscan2
- F10 | c.1265C>T p.P422L | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1210141004, CM042982, COSV100979152, COSV65021331; called by muse, mutect2, varscan2
- FAM114A2 | c.232C>A p.P78T | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV59456894; called by muse, mutect2, varscan2
- FAM135B | c.3841A>T p.T1281S | Missense Mutation (SNP) | VAF 19/197 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52740526; called by muse, mutect2
- FAM169A | c.403C>A p.P135T | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65846926; called by muse, mutect2, varscan2
- FAP | c.914G>T p.C305F | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.546); catalogued as COSV51864866; called by muse, mutect2, varscan2
- FAT1 | c.7579G>T p.V2527F | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as rs373112377, COSV71675202; called by muse, mutect2, varscan2
- FBN2 | c.748C>A p.P250T | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV52530637; called by muse, mutect2, varscan2
- FBN3 | c.8321G>T p.R2774L | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs139098536, COSV53664645; called by muse, mutect2, varscan2
- FBXW7 | c.1859C>G p.P620R (on ENST00000281708 / NM_001349798.2; = p.P540R on NM_018315.5) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.679); catalogued as COSV55897299, COSV55936944; called by muse, mutect2
- FCER1A | c.23C>A p.P8H | Missense Mutation (SNP) | VAF 24/362 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV63667881; called by muse, mutect2
- FGFR1 | c.1939G>A p.D647N (on ENST00000447712 / NM_023110.3; = p.D645N on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1388442293, COSV58340270; called by muse, mutect2, varscan2
- FHDC1 | c.2381G>C p.R794T | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.01); catalogued as COSV52601678; called by muse, mutect2, varscan2
- FLG | c.4003G>T p.E1335* | Nonsense Mutation (SNP) | VAF 48/800 reads (6%) | catalogued as COSV64243394; called by muse, mutect2
- FLG | c.2671A>C p.S891R | Missense Mutation (SNP) | VAF 62/1062 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1476265194, COSV100910462, COSV64239905; called by muse, mutect2
- FLNC | c.620A>T p.E207V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as COSV100367703; called by muse, mutect2
- FLT4 | c.478G>T p.V160L | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.533); catalogued as COSV56116376; called by muse, mutect2, varscan2
- FRAS1 | c.7454C>G p.T2485R | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.186); catalogued as COSV53589559, COSV53629669; called by muse, mutect2, varscan2
- FRMD6 | c.1139G>T p.R380L (on ENST00000344768 / NM_001267046.2; = p.R372L on NM_152330.4) | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.709); catalogued as COSV61089732; called by muse, mutect2, varscan2
- FSCB | c.1061C>T p.S354L | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0.018); catalogued as COSV61218991; called by muse, mutect2
- FSIP2 | c.17476G>A p.D5826N | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.203); catalogued as rs757564095, COSV100554283; called by muse, mutect2, varscan2
- FSTL5 | c.1300G>T p.A434S | Missense Mutation (SNP) | VAF 30/253 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as COSV60212797; called by muse, mutect2, varscan2
- GABBR1 | c.160A>G p.I54V | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs1352245485, COSV63543675; called by muse, mutect2
- GABPA | c.1150G>T p.G384W | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61395595; called by muse, mutect2, varscan2
- GABRA2 | c.276C>A p.F92L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62917164; called by muse, mutect2, varscan2
- GABRG1 | c.709C>T p.Q237* | Nonsense Mutation (SNP) | VAF 5/46 reads (11%) | catalogued as COSV54958349, COSV54960657; called by muse, mutect2, varscan2
- GABRG1 | c.83T>C p.L28P | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV54958359; called by muse, mutect2
- GALNTL6 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.907); catalogued as rs752243982, COSV72491188; called by muse, mutect2
- GLYATL1 | c.94T>C p.Y32H (on ENST00000317391 / NM_001354699.1; = p.Y63H on NM_080661.4) | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV55610206; called by muse, mutect2, varscan2
- GPATCH4 | c.941G>A p.G314E | Missense Mutation (SNP) | VAF 46/500 reads (9%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV58040836; called by muse, mutect2
- GPATCH8 | c.2315G>T p.G772V | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.116); catalogued as COSV100132499; called by muse, mutect2
- GPR139 | c.642C>A p.S214R | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.053); catalogued as COSV58503930; called by muse, mutect2, varscan2
- GPR158 | c.1703T>G p.L568R | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV66276901; called by muse, mutect2, varscan2
- GPRASP2 | c.202G>C p.A68P | Missense Mutation (SNP) | VAF 57/160 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV59992018; called by muse, mutect2, varscan2
- GPRC6A | c.1393G>A p.D465N | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.255); catalogued as COSV59953206, COSV59954730; called by muse, mutect2, varscan2
- GRIA2 | c.1715G>A p.W572* | Nonsense Mutation (SNP) | VAF 14/121 reads (12%) | catalogued as COSV52398635; called by muse, mutect2, varscan2
- GRIN3A | c.1834C>A p.H612N | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as COSV62456354; called by muse, mutect2, varscan2
- GRPR | c.803T>A p.V268E | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66669925; called by muse, mutect2, varscan2
- GZF1 | c.1906G>C p.D636H | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV57637146; called by muse, mutect2, varscan2
- HADHB | c.713G>C p.R238P | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58547490; called by muse, mutect2, varscan2
- HCK | c.1016G>A p.G339E | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52941173, COSV52945324; called by muse, mutect2
- HEPH | c.2209A>G p.I737V (on ENST00000343002; = p.I470V on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as rs1167190057, COSV57968186; called by muse, mutect2, varscan2
- HERC2 | c.13889A>G p.Y4630C | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55337916; called by muse, mutect2, varscan2
- HFM1 | c.2935A>G p.K979E | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.681); catalogued as COSV54032990; called by muse, mutect2, varscan2
- HK2 | c.2735G>T p.R912L | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.07); catalogued as COSV51877435; called by muse, mutect2
- HORMAD1 | c.82G>T p.V28L | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.07); catalogued as COSV100463881; called by muse, mutect2
- HORMAD1 | c.81G>T p.L27F | Missense Mutation (SNP) | VAF 16/241 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100463886; called by muse, mutect2
- HOXB6 | c.547del p.L183Cfs*3 | Frame Shift Del (DEL) | VAF 28/233 reads (12%) | catalogued as COSV53313710; called by mutect2, pindel, varscan2
- HRNR | c.970C>T p.Q324* | Nonsense Mutation (SNP) | VAF 10/163 reads (6%) | catalogued as COSV64260581; called by muse, mutect2
- HS3ST3A1 | c.568C>G p.R190G | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs78372491, COSV52377261; called by muse, varscan2
- HSPA1A | c.100G>A p.G34S | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1344138338, COSV100989339; called by muse, mutect2
- IFI44 | c.644C>G p.T215R | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100877328, COSV66075208; called by muse, mutect2, varscan2
- IFNB1 | c.109C>A p.Q37K | Missense Mutation (SNP) | VAF 39/67 reads (58%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as COSV101207777, COSV66525692; called by muse, mutect2, varscan2
- IGDCC4 | c.2536+2T>C p.X846_splice | Splice Site (SNP) | VAF 10/35 reads (29%) | catalogued as COSV61538329; called by muse, mutect2, varscan2
- IGF2BP3 | c.644G>T p.G215V | Missense Mutation (SNP) | VAF 45/153 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV51685206; called by muse, mutect2, varscan2
- IGHV2-70 | c.305C>A p.T102K | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs369201986; called by muse, mutect2, varscan2
- IGKV1-5 | c.48G>T p.W16C | Missense Mutation (SNP) | VAF 65/191 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as rs774100906; called by muse, mutect2, varscan2
- IL24 | c.454C>A p.Q152K | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.05); catalogued as COSV54321184; called by muse, mutect2, varscan2
- IL36G | c.419T>A p.I140N | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52078923; called by muse, mutect2, varscan2
- INHBA | c.149C>A p.S50Y | Missense Mutation (SNP) | VAF 74/1044 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.452); catalogued as rs779271157, COSV54223438; called by muse, mutect2
- INPP4B | c.1069A>T p.K357* | Nonsense Mutation (SNP) | VAF 8/65 reads (12%) | catalogued as COSV53712570, COSV53736195; called by muse, mutect2, varscan2
- INPP4B | c.558G>T p.M186I | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.939); catalogued as COSV53711343, COSV53728539; called by muse, mutect2
- INTS3 | c.3085C>T p.R1029W | Missense Mutation (SNP) | VAF 30/322 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs753177049, COSV55164849; called by muse, mutect2
- INTS9 | c.750G>A p.M250I | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.074); catalogued as COSV68435199; called by muse, mutect2, varscan2
- IPP | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as rs1249428961, COSV63433237; called by muse, mutect2, varscan2
- ITGA4 | c.1013G>T p.R338I | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51998303, COSV52002278, COSV52003390; called by muse, mutect2, varscan2
- ITGAD | c.1627C>A p.P543T | Missense Mutation (SNP) | VAF 68/381 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV66759030; called by muse, mutect2, varscan2
- ITGAX | c.537C>A p.S179R | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.025); catalogued as COSV51648750; called by muse, mutect2, varscan2
- KAT14 | c.259+1G>T p.X87_splice | Splice Site (SNP) | VAF 7/28 reads (25%) | catalogued as COSV66606793; called by muse, mutect2
- KCND3 | c.1965G>T p.L655F | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV56185386; called by muse, mutect2, varscan2
- KCNK2 | c.253C>A p.Q85K (on ENST00000444842 / NM_001017425.3; = p.Q70K on NM_014217.4) | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.082); catalogued as rs1367707521, COSV67208103; called by muse, mutect2, varscan2
- KCTD16 | c.425C>A p.A142D | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0.03); catalogued as COSV72578812; called by muse, mutect2, varscan2
- KHDRBS2 | c.608C>T p.S203L | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.05); catalogued as COSV55434527; called by muse, mutect2, varscan2
- KIF19 | c.1900G>T p.E634* | Nonsense Mutation (SNP) | VAF 18/44 reads (41%) | catalogued as COSV63430079; called by muse, mutect2, varscan2
- KIF2B | c.397G>A p.V133M | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs1305227589, COSV52127518, COSV52133387; called by muse, mutect2, varscan2
- KIF2C | c.1999G>T p.E667* | Nonsense Mutation (SNP) | VAF 23/50 reads (46%) | catalogued as COSV64765209; called by muse, mutect2, varscan2
- KLF12 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.743); catalogued as rs200541651, COSV66577499; called by muse, mutect2, varscan2
- KRT25 | c.633T>A p.S211R | Missense Mutation (SNP) | VAF 50/246 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs920579512, COSV56445874; called by muse, mutect2, varscan2
- KRT76 | c.1709G>A p.R570K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as rs772226528; called by muse, varscan2
- KRTAP11-1 | c.446G>A p.R149K | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.178); catalogued as COSV100190532; called by muse, mutect2, varscan2
- KRTAP4-2 | c.154C>A p.Q52K | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.949); catalogued as COSV100894522; called by muse, mutect2, varscan2
- LAMA2 | c.3854G>T p.R1285I | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.043); catalogued as COSV70352177; called by muse, mutect2, varscan2
- LAMA2 | c.6850C>A p.L2284M | Missense Mutation (SNP) | VAF 35/439 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV70352179; called by muse, mutect2
- LAMA3 | c.8753T>G p.L2918R (on ENST00000313654 / NM_198129.4; = p.L1309R on NM_000227.6) | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.085); catalogued as COSV52539076; called by muse, mutect2, varscan2
- LAMA4 | c.2722T>C p.Y908H (on ENST00000230538 / NM_001105206.3; = p.Y901H on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/79 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57901673; called by muse, mutect2
- LAMC2 | c.571G>A p.G191R | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51457957; called by muse, mutect2, varscan2
- LAMC3 | c.4621C>A p.L1541M | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.719); catalogued as COSV55990725; called by muse, mutect2, varscan2
- LAYN | c.524G>A p.R175Q (on ENST00000375615 / NM_001258390.1; = p.R167Q on NM_178834.5) | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.177); catalogued as rs760454342, COSV100986260, COSV65105239; called by muse, mutect2, varscan2
- LIFR | c.482G>A p.G161D | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54695395, COSV99664793; called by muse, mutect2
- LRP1 | c.4723A>T p.N1575Y | Missense Mutation (SNP) | VAF 82/173 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV54519265; called by muse, mutect2, varscan2
- LRP1B | c.11486G>T p.C3829F | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67250965; called by muse, mutect2, varscan2
- LRP2 | c.9024G>C p.K3008N | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV55564234; called by muse, mutect2
- LRRC43 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60291612; called by muse, mutect2, varscan2
- LRRC7 | c.1653G>C p.Q551H (on ENST00000651989 / NM_001370785.2; = p.Q518H on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV50524574; called by muse, mutect2, varscan2
- LRRC7 | c.3548G>T p.R1183I (on ENST00000651989 / NM_001370785.2; = p.R1150I on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.524); catalogued as COSV50410542, COSV50524891; called by muse, mutect2
- LRRK2 | c.1328T>C p.L443P | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV54162291; called by muse, mutect2
- LUZP1 | c.3058C>T p.H1020Y | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.439); catalogued as COSV56503534; called by muse, mutect2
- LVRN | c.1489C>G p.L497V | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.432); catalogued as COSV63497839; called by muse, mutect2, varscan2
- LY6K | c.72A>T p.R24S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.33); catalogued as COSV99456168; called by muse, mutect2, varscan2
- LY75 | c.2086G>T p.E696* | Nonsense Mutation (SNP) | VAF 14/194 reads (7%) | catalogued as COSV55110015, COSV55112995; called by muse, mutect2
- LY86 | c.73A>G p.K25E | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs75006006; called by muse, mutect2, varscan2
- MAGEE1 | c.812C>T p.S271F | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.075); catalogued as COSV63911254; called by muse, mutect2, varscan2
- MAML1 | c.1471A>T p.S491C | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV52987534; called by muse, mutect2, varscan2
- MAPK9 | c.292C>G p.L98V | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.07); catalogued as COSV58124043; called by muse, mutect2, varscan2
- MARCHF11 | c.884T>C p.I295T | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV60131939; called by muse, mutect2, varscan2
- MED13L | c.4953G>T p.E1651D | Missense Mutation (SNP) | VAF 62/108 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV56125416; called by muse, mutect2, varscan2
- MFAP5 | c.59-1G>T p.X20_splice | Splice Site (SNP) | VAF 10/48 reads (21%) | catalogued as COSV63945161; called by muse, mutect2, varscan2
- MFN2 | c.886C>T p.Q296* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as COSV52424046; called by muse, mutect2, varscan2
- MFSD6 | c.1764G>A p.M588I | Missense Mutation (SNP) | VAF 67/160 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as COSV55624030; called by muse, mutect2, varscan2
- MGAM | c.5509G>C p.D1837H | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as COSV72074272, COSV72075163; called by muse, mutect2, varscan2
- MINAR1 | c.145G>C p.V49L | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59584868; called by muse, mutect2, varscan2
- MKS1 | c.845G>C p.R282P | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.592); catalogued as COSV58305323; called by muse, mutect2, varscan2
- MLF2 | c.127A>T p.I43F | Missense Mutation (SNP) | VAF 21/222 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV52571759; called by muse, mutect2
- MMP16 | c.282-1G>A p.X94_splice | Splice Site (SNP) | VAF 20/99 reads (20%) | catalogued as COSV54154856; called by mutect2, varscan2
- MMP2 | c.1785G>T p.K595N | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.577); catalogued as rs757888862, COSV54603457; called by mutect2, varscan2
- MMP9 | c.129G>C p.Q43H | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV64885523; called by muse, mutect2, varscan2
- MOGAT3 | c.520C>A p.L174M | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56175802; called by muse, mutect2, varscan2
- MOXD1 | c.1542A>T p.Q514H | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as COSV60946467; called by muse, mutect2, varscan2
- MRI1 | c.1039G>T p.E347* (on ENST00000040663 / NM_001031727.4; = p.E300* on NM_032285.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 21/71 reads (30%) | catalogued as COSV50003564, COSV99237275; called by muse, mutect2, varscan2
- MROH9 | c.1244C>T p.A415V | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.073); catalogued as rs748891805, COSV63010002; called by muse, mutect2, varscan2
- MRPL2 | c.430G>T p.G144W | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99431466; called by muse, mutect2, varscan2
- MRPS30 | c.1258C>T p.Q420* | Nonsense Mutation (SNP) | VAF 5/38 reads (13%) | catalogued as COSV50181826; called by muse, mutect2, varscan2
- MSH4 | c.2504A>T p.K835M | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV54207642; called by muse, mutect2, varscan2
- MSLN | c.473A>T p.E158V | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as COSV53504364; called by muse, mutect2, varscan2
- MTHFD1L | c.2859G>T p.M953I | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.138); catalogued as COSV100944984, COSV66226508; called by muse, mutect2, varscan2
- MTMR6 | c.401A>G p.Y134C | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs769522305, COSV67809119; called by muse, mutect2, varscan2
- MTNR1B | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.035); catalogued as rs148152472; called by muse, mutect2, varscan2
- MUC16 | c.38671C>A p.L12891I | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.992); catalogued as COSV67480128; called by muse, mutect2, varscan2
- MUC16 | c.35227G>A p.V11743M | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.192); catalogued as rs551319234, COSV67480130; called by muse, mutect2, varscan2
- MUC16 | c.35140G>A p.D11714N | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.148); catalogued as COSV67463118, COSV67480138; called by muse, mutect2, varscan2
- MUC16 | c.32732C>A p.T10911N | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV101198482, COSV101202177; called by muse, mutect2, varscan2
- MUC16 | c.15220T>A p.S5074T | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.006); catalogued as COSV67480147; called by muse, mutect2, varscan2
- MUC17 | c.9044G>T p.S3015I | Missense Mutation (SNP) | VAF 38/884 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as COSV100070926, COSV60296532; called by muse, mutect2
- MUTYH | c.851C>A p.A284D | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58344700; called by muse, mutect2, varscan2
- MYH1 | c.4796A>T p.E1599V | Missense Mutation (SNP) | VAF 24/238 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56853174; called by muse, mutect2
- MYH10 | c.2664G>C p.E888D | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.53); catalogued as COSV52606353; called by muse, mutect2
- MYH3 | c.304G>A p.V102M | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs983358916, COSV56867758; called by muse, mutect2, varscan2
- MYH8 | c.2172-2A>T p.X724_splice | Splice Site (SNP) | VAF 23/97 reads (24%) | catalogued as COSV67969263; called by muse, mutect2, varscan2
- MYO18A | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs370927481; called by muse, mutect2, varscan2
- MYO7B | c.1035C>A p.D345E | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV67345136, COSV67349655; called by muse, mutect2
- MYOCD | c.608C>T p.S203L | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV58507912; called by muse, mutect2, varscan2
- NAALAD2 | c.1045G>T p.V349F | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.262); catalogued as COSV58963705; called by muse, mutect2
- NAV3 | c.1320del p.V442Cfs*50 | Frame Shift Del (DEL) | VAF 49/164 reads (30%) | catalogued as COSV57064769; called by mutect2, pindel, varscan2
- NETO1 | c.703G>T p.A235S | Missense Mutation (SNP) | VAF 86/182 reads (47%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.584); catalogued as rs898864719, COSV55011102; called by muse, mutect2, varscan2
- NFATC1 | c.1959+1G>T p.X653_splice | Splice Site (SNP) | VAF 13/54 reads (24%) | catalogued as COSV53699608, COSV53704994; called by muse, mutect2, varscan2
- NLRP3 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.454); catalogued as rs778304232, COSV60226409, COSV60228660; called by mutect2, varscan2
- NMD3 | c.326G>T p.R109I | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63618989; called by muse, mutect2, varscan2
- NMUR2 | c.499C>A p.L167I | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV54921157; called by muse, mutect2, varscan2
- NOD2 | c.830G>T p.G277V | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as rs1437917228, COSV56053189; called by muse, mutect2, varscan2
- NOL6 | c.1297A>T p.T433S | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.536); catalogued as COSV53043860; called by muse, mutect2, varscan2
- NOTCH4 | c.4190C>T p.P1397L | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.095); catalogued as rs753178549, COSV100900675, COSV66681461; called by muse, mutect2, varscan2
- NOVA1 | c.1249A>G p.T417A | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT tolerated (0.97); PolyPhen benign (0.033); catalogued as COSV57482777; called by muse, mutect2
- NPAS4 | c.1115G>T p.S372I | Missense Mutation (SNP) | VAF 51/291 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV60651722, COSV60652742; called by muse, mutect2, varscan2
- NPR1 | c.1252G>T p.G418C | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV64142517; called by muse, mutect2
- NPY2R | c.548T>A p.L183Q | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); catalogued as COSV61528963; called by muse, mutect2
- NR5A2 | c.676A>T p.N226Y (on ENST00000367362 / NM_205860.3; = p.N180Y on NM_003822.5) | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.078); catalogued as COSV52654147; called by muse, mutect2
- NRG3 | c.1522C>T p.P508S | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as COSV64574645; called by muse, mutect2, varscan2
- NRXN1 | c.2422G>C p.E808Q | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.066); catalogued as COSV58474502; called by muse, varscan2
- NRXN1 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.073); catalogued as COSV68019551; called by muse, mutect2
- NSUN2 | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 18/183 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52955914; called by muse, mutect2, varscan2
- NTM | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 43/211 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV66186875; called by muse, mutect2, varscan2
- NTRK1 | c.1430C>A p.S477Y | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as rs991568934, COSV62324843, COSV62327248; called by muse, mutect2
- NUP210 | c.725A>C p.N242T | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54410121; called by muse, mutect2
- OLFML3 | c.1021A>T p.S341C | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV57436483; called by muse, mutect2
- OR10G9 | c.431C>A p.A144D | Missense Mutation (SNP) | VAF 32/222 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV66686538; called by muse, mutect2, varscan2
- OR10X1 | c.892C>A p.L298I | Missense Mutation (SNP) | VAF 48/313 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63766873; called by muse, mutect2, varscan2
- OR2H2 | c.56C>A p.P19Q | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100589497; called by muse, mutect2
- OR4A15 | c.175T>A p.F59I | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.887); catalogued as rs749271641, COSV59036475; called by muse, mutect2, varscan2
- OR4A47 | c.730G>T p.V244L | Missense Mutation (SNP) | VAF 69/294 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV71444921; called by muse, mutect2, varscan2
- OR4C15 | c.346T>G p.L116V (on ENST00000314644; = p.L62V on NM_001001920.2) | Missense Mutation (SNP) | VAF 18/241 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV58952394, COSV58952408, COSV58954071; called by muse, mutect2
- OR52K1 | c.922C>A p.L308I | Missense Mutation (SNP) | VAF 70/177 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1248286553, COSV56904261; called by muse, mutect2, varscan2
- OR56B1 | c.360G>T p.E120D | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57723556; called by muse, mutect2, varscan2
- OR6K6 | c.582G>T p.L194F (on ENST00000368144; = p.L170F on NM_001005184.1) | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63744555; called by muse, mutect2
- OR8H1 | c.267C>A p.N89K | Missense Mutation (SNP) | VAF 68/384 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100476886; called by muse, mutect2, varscan2
- OR8H3 | c.23C>A p.T8K | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV57908838; called by muse, mutect2
- OS9 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 38/177 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV57783980, COSV99232620; called by muse, mutect2, varscan2
- OTUD4 | c.1321G>T p.G441C (on ENST00000447906 / NM_001366057.1; = p.G376C on NM_001102653.1) | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71382084; called by muse, mutect2, varscan2
- PADI1 | c.1958C>A p.P653H | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64934904; called by muse, mutect2, varscan2
- PAK5 | c.1375T>A p.S459T | Missense Mutation (SNP) | VAF 90/274 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62033093; called by muse, mutect2, varscan2
- PALLD | c.1787G>A p.R596K | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54987896, COSV54989872; called by muse, mutect2, varscan2
- PARP9 | c.1476G>C p.L492F | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV64451329; called by muse, mutect2, varscan2
- PAX4 | c.574G>T p.G192W | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV58390056; called by muse, mutect2, varscan2
- PCDH10 | c.508G>C p.D170H | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52099542; called by muse, mutect2
- PCDH15 | c.2091G>T p.G697= | Splice Region (SNP) | VAF 12/101 reads (12%) | catalogued as COSV57355107; called by muse, mutect2
- PCDHA1 | c.2254C>T p.Q752* | Nonsense Mutation (SNP) | VAF 9/33 reads (27%) | catalogued as COSV65375778; called by muse, mutect2, varscan2
- PCDHA10 | c.1462C>A p.L488M | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV56527503; called by muse, mutect2, varscan2
- PCDHA12 | c.1702A>G p.T568A | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV56527527; called by muse, mutect2
- PCDHA13 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.139); catalogued as rs868963567, COSV56502477; called by muse, mutect2, varscan2
- PCDHB1 | c.1612G>T p.G538C | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60632248; called by muse, mutect2, varscan2
- PCDHB15 | c.1285C>A p.P429T | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50892401; called by muse, mutect2, varscan2
- PCDHB15 | c.1286C>A p.P429Q | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51426536, COSV99178837; called by muse, mutect2, varscan2
- PCDHB4 | c.819C>A p.F273L | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.049); catalogued as COSV52021919, COSV52024846; called by muse, mutect2, varscan2
- PCDHB6 | c.711C>A p.N237K | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV50702286, COSV50709742; called by muse, mutect2, varscan2
- PCDHGC3 | c.536A>G p.Y179C | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV52759314; called by muse, mutect2
- PCLO | c.13964C>A p.T4655K | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.387); catalogued as COSV61651617; called by muse, mutect2
- PCNX1 | c.4814G>C p.G1605A | Missense Mutation (SNP) | VAF 39/331 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53098150; called by muse, mutect2, varscan2
- PDE2A | c.2108C>G p.T703R | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57810716; called by muse, mutect2, varscan2
- PDHA2 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.156); catalogued as rs1016023529, COSV54777014; called by muse, mutect2
- PDZRN4 | c.2695C>G p.R899G (on ENST00000402685 / NM_001164595.2; = p.R641G on NM_013377.4) | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54209543, COSV54218950; called by muse, mutect2, varscan2
- PGBD2 | c.242G>T p.C81F | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV61400577, COSV61400668; called by muse, mutect2, varscan2
- PGK2 | c.841A>T p.T281S | Missense Mutation (SNP) | VAF 31/295 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.207); catalogued as COSV59164749; called by muse, mutect2, varscan2
- PGLYRP4 | c.824+1G>T p.X275_splice | Splice Site (SNP) | VAF 71/165 reads (43%) | catalogued as COSV62835889; called by muse, mutect2, varscan2
- PHF20L1 | c.894G>T p.K298N | Missense Mutation (SNP) | VAF 11/198 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV55195571; called by muse, mutect2
- PIK3AP1 | c.1471+1G>T p.X491_splice | Splice Site (SNP) | VAF 58/256 reads (23%) | catalogued as rs1405147884, COSV59534738; called by muse, mutect2, varscan2
- PIP | c.26G>T p.R9M | Missense Mutation (SNP) | VAF 100/747 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as COSV52121119; called by muse, mutect2, varscan2
- PKD1L1 | c.6736-2A>T p.X2246_splice | Splice Site (SNP) | VAF 6/54 reads (11%) | catalogued as COSV56972143; called by muse, mutect2, varscan2
- PKHD1L1 | c.7777G>C p.D2593H | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV65737548, COSV65748073; called by muse, mutect2
- PKMYT1 | c.454G>T p.A152S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0.011); catalogued as COSV51892063; called by muse, mutect2, varscan2
- PKN3 | c.1834G>C p.E612Q | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.26); catalogued as COSV52578354; called by muse, mutect2, varscan2
- PLCG2 | c.2435G>T p.G812V | Missense Mutation (SNP) | VAF 37/244 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100842097; called by muse, mutect2, varscan2
- PLEKHH2 | c.811A>T p.T271S | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV56757772; called by muse, mutect2
- PLG | c.1070T>A p.V357E | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV51984758; called by muse, mutect2
- PLK1 | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 40/438 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs146806568; called by muse, mutect2
- PLK4 | c.2669C>G p.S890C | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV54638550; called by muse, mutect2
- PLOD2 | c.951A>G p.I317M | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs1420933542, COSV51467022; called by muse, mutect2, varscan2
- PLPPR5 | c.118G>A p.V40M | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.372); catalogued as rs766371899, COSV54176026; called by muse, mutect2, varscan2
- PLXNA4 | c.3084C>G p.I1028M | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as rs747206524, COSV58145639, COSV58150677; called by muse, mutect2, varscan2
- PLXNB3 | c.3479G>T p.R1160L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.258); catalogued as COSV62799909; called by muse, mutect2, varscan2
- PNPLA6 | c.3744G>T p.Q1248H (on ENST00000414982 / NM_001166111.2; = p.Q1200H on NM_006702.5) | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV55381964; called by muse, mutect2, varscan2
- POLR2H | c.115C>G p.L39V | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV55602948; called by muse, mutect2, varscan2
- PPP1R9A | c.553A>G p.T185A | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV56902196; called by muse, mutect2
- PPP2R2A | c.235A>G p.S79G | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60098153; called by muse, mutect2, varscan2
- PRAMEF2 | c.154C>A p.L52M | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV53577488; called by muse, mutect2, varscan2
- PRDM9 | c.2340G>T p.E780D | Missense Mutation (SNP) | VAF 84/230 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.187); catalogued as COSV57010191; called by muse, varscan2
- PRKAR1B | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV64319148; called by muse, mutect2, varscan2
- PRKCB | c.1557del p.K520Sfs*39 | Frame Shift Del (DEL) | VAF 16/205 reads (8%) | catalogued as COSV100331981; called by mutect2, pindel
- PRR23B | c.735C>A p.H245Q | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.085); catalogued as COSV61493461, COSV61494304; called by muse, mutect2, varscan2
- PRSS1 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 50/472 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.498); catalogued as rs760120835, COSV61194938; called by muse, varscan2
- PRUNE2 | c.286C>G p.Q96E | Missense Mutation (SNP) | VAF 90/163 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as COSV65028644; called by muse, mutect2, varscan2
- PSG3 | c.1162C>T p.H388Y | Missense Mutation (SNP) | VAF 134/280 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.53); catalogued as COSV59505751; called by muse, mutect2, varscan2
- PSG8 | c.817T>A p.W273R | Missense Mutation (SNP) | VAF 116/273 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60613741; called by muse, mutect2, varscan2
- PSMD12 | c.958C>A p.L320I | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.057); catalogued as COSV62066362; called by muse, mutect2, varscan2
- PTCHD3 | c.1174A>T p.I392F | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV71257148; called by muse, mutect2, varscan2
- PTGS1 | c.415G>T p.E139* | Nonsense Mutation (SNP) | VAF 50/95 reads (53%) | catalogued as COSV56293453; called by muse, mutect2, varscan2
- PTH2R | c.4G>C p.A2P | Missense Mutation (SNP) | VAF 76/285 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV55918228; called by muse, mutect2, varscan2
- PTH2R | c.1034G>T p.W345L | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.944); catalogued as rs151296979; called by muse, mutect2, varscan2
- PTPRJ | c.3770A>G p.Y1257C | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.989); catalogued as COSV69253496; called by muse, mutect2, varscan2
- PTPRN2 | c.2935G>A p.E979K | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67030743; called by muse, mutect2
- PTPRN2 | c.1788+1G>T p.X596_splice | Splice Site (SNP) | VAF 114/383 reads (30%) | catalogued as COSV67051238; called by muse, mutect2, varscan2
- PXDNL | c.806A>C p.H269P | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.745); catalogued as COSV62482641, COSV62493653; called by muse, mutect2, varscan2
- QRICH2 | c.1732C>T p.R578C | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.188); catalogued as rs752868487, COSV53153065, COSV53155624; called by muse, mutect2, varscan2
- RAB41 | c.79C>A p.Q27K | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV52104773; called by muse, mutect2, varscan2
- RABGGTA | c.648G>C p.Q216H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as COSV53771205; called by muse, mutect2
- RAD9A | c.333G>T p.Q111H | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV57237569; called by muse, mutect2, varscan2
- RBM45 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.934); catalogued as COSV53721832; called by muse, mutect2
- RBP2 | c.104T>A p.V35E | Missense Mutation (SNP) | VAF 40/199 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.092); catalogued as COSV51674371; called by muse, mutect2, varscan2
- RELN | c.9623G>T p.W3208L | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV59020637; called by muse, mutect2, varscan2
- RETNLB | c.213G>T p.M71I | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.131); catalogued as COSV55466000, COSV55466437; called by muse, mutect2, varscan2
- REV3L | c.4273A>T p.S1425C | Missense Mutation (SNP) | VAF 23/211 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.72); catalogued as COSV62621408; called by muse, mutect2, varscan2
- RHBDD1 | c.810A>T p.E270D | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.685); catalogued as COSV58129280; called by muse, mutect2, varscan2
- RHBDF2 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57421623; called by muse, mutect2, varscan2
- RIF1 | c.6238A>T p.I2080F | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.039); catalogued as COSV54620819; called by muse, mutect2, varscan2
- RIN3 | c.1195G>T p.D399Y | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV53652568; called by muse, mutect2, varscan2
- RNASE12 | c.366C>G p.H122Q | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as COSV100250455; called by muse, mutect2
- RNF111 | c.37A>G p.T13A | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.05); catalogued as COSV62088290; called by muse, mutect2
- RNF138 | c.719C>G p.S240C | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV55234883, COSV55235735; called by muse, mutect2, varscan2
- RNF212 | c.491C>G p.S164C | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as rs760474654, COSV101260158; called by muse, mutect2, varscan2
- RORB | c.373G>T p.E125* (on ENST00000396204 / NM_001365023.1; = p.E114* on NM_006914.4) | Nonsense Mutation (SNP) | VAF 22/54 reads (41%) | catalogued as COSV65338295; called by muse, mutect2, varscan2
- RP1L1 | c.731T>C p.L244P | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as COSV100261713; called by muse, mutect2, varscan2
- RRM1 | c.478A>C p.N160H | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.046); catalogued as COSV56165223; called by muse, mutect2, varscan2
- RRN3 | c.1200G>T p.R400S | Missense Mutation (SNP) | VAF 27/252 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1397316127, COSV52215787; called by muse, mutect2, varscan2
- RSPO2 | c.401C>A p.P134Q | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as COSV52650268; called by muse, mutect2, varscan2
- RTL9 | c.1565C>A p.T522K | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.892); catalogued as rs746253760, COSV101511643; called by muse, mutect2, varscan2
- RTTN | c.5186-1G>T p.X1729_splice | Splice Site (SNP) | VAF 12/21 reads (57%) | catalogued as COSV55348703; called by muse, mutect2, varscan2
- RUFY1 | c.1535G>A p.R512K | Missense Mutation (SNP) | VAF 28/280 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as COSV60162311; called by muse, mutect2
- RYR2 | c.6418A>T p.K2140* | Nonsense Mutation (SNP) | VAF 16/75 reads (21%) | catalogued as COSV63699959; called by muse, mutect2, varscan2
- RYR2 | c.12400G>T p.G4134C | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63683791; called by muse, varscan2
- RYR2 | c.12538G>T p.G4180C | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as COSV63699981; called by muse, varscan2
- SAMD3 | c.1419T>A p.F473L | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV62387542; called by muse, mutect2, varscan2
- SAMD9 | c.2941G>T p.V981L | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as COSV66076768; called by muse, varscan2
- SATB2 | c.564G>T p.Q188H | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV53489218; called by muse, mutect2, varscan2
- SCAF8 | c.1954G>T p.V652F | Missense Mutation (SNP) | VAF 34/199 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV63200291; called by muse, mutect2, varscan2
- SCN10A | c.3145G>T p.G1049C | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV71862265; called by muse, mutect2, varscan2
- SCN1A | c.1189A>T p.K397* | Nonsense Mutation (SNP) | VAF 27/135 reads (20%) | catalogued as rs1553546942, COSV57679285; called by muse, mutect2, varscan2
- SCN2A | c.991G>T p.G331W | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV51849228; called by muse, mutect2
- SCN2A | c.3064C>A p.R1022S | Missense Mutation (SNP) | VAF 35/256 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.44); catalogued as COSV51834401, COSV51849249; called by muse, mutect2, varscan2
- SCYL1 | c.1624G>C p.E542Q | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.403); catalogued as COSV54214184; called by muse, mutect2
- SCYL2 | c.8C>A p.S3Y | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.031); catalogued as COSV62568616; called by muse, mutect2, varscan2
- SDC1 | c.896A>T p.Y299F | Missense Mutation (SNP) | VAF 87/208 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54340846; called by muse, mutect2, varscan2
- SEC61A2 | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV53653756, COSV53655892; called by muse, mutect2, varscan2
- SEMA3E | c.761A>T p.E254V | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV57100293; called by muse, mutect2, varscan2
- SEPTIN1 | c.511C>G p.L171V (on ENST00000321367; = p.L124V on NM_052838.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as COSV58443009; called by muse, mutect2, varscan2
- SEPTIN8 | c.251G>T p.R84L | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.476); catalogued as COSV51524630; called by muse, mutect2, varscan2
- SERPINB11 | c.1031C>G p.T344R | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101236157; called by muse, mutect2, varscan2
- SERPINB13 | c.915G>T p.M305I | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV54029942; called by muse, mutect2, varscan2
- SERPINB3 | c.828A>T p.R276S | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as COSV52192970; called by muse, mutect2, varscan2
- SERTAD2 | c.680G>C p.G227A | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV57640871; called by muse, mutect2, varscan2
- SETBP1 | c.4010G>T p.S1337I | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV56327622, COSV56330021, COSV56334961; called by muse, mutect2, varscan2
- SHF | c.217G>A p.G73R | Missense Mutation (SNP) | VAF 56/199 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV52051745; called by muse, mutect2, varscan2
- SIGLEC9 | c.542T>C p.I181T | Missense Mutation (SNP) | VAF 77/143 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV51586314; called by muse, mutect2, varscan2
- SIRPG | c.615C>A p.Y205* | Nonsense Mutation (SNP) | VAF 32/101 reads (32%) | catalogued as COSV53808925; called by muse, mutect2, varscan2
- SLC14A1 | c.443T>C p.L148P | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.213); catalogued as COSV58933245; called by muse, mutect2, varscan2
- SLC1A6 | c.340A>T p.T114S | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (0.59); PolyPhen benign (0.028); catalogued as COSV55672270, COSV99694092; called by muse, mutect2, varscan2
- SLC22A2 | c.481T>C p.F161L | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT tolerated (0.89); PolyPhen benign (0.06); catalogued as rs8177509; called by muse, mutect2, varscan2
- SLC26A4 | c.872G>T p.R291L | Missense Mutation (SNP) | VAF 29/244 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs138816005, COSV55918385; called by muse, mutect2, varscan2
- SLC2A13 | c.1658G>T p.W553L | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55123446; called by muse, mutect2, varscan2
- SLC35G3 | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 54/240 reads (23%) | catalogued as COSV99268315; called by muse, mutect2, varscan2
- SLC43A3 | c.271A>G p.I91V | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.336); catalogued as COSV61450899; called by mutect2, varscan2
- SLC44A5 | c.1480G>T p.D494Y | Missense Mutation (SNP) | VAF 15/161 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV63769674; called by muse, mutect2, varscan2
- SLC5A8 | c.919G>T p.D307Y | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV73310939; called by muse, mutect2, varscan2
- SLC5A8 | c.790G>C p.V264L | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV73310940, COSV73311283; called by muse, mutect2
- SLC5A9 | c.1702C>T p.R568W | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as rs138580488, COSV52585419; called by muse, mutect2, varscan2
- SLC7A13 | c.1077G>T p.L359F | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52535987; called by muse, mutect2, varscan2
- SLC7A7 | c.604G>T p.G202C | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53541747; called by muse, mutect2, varscan2
- SLC8A3 | c.1234G>T p.G412W | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63524322; called by muse, mutect2, varscan2
- SLC9A6 | c.803+1G>T p.X268_splice | Splice Site (SNP) | VAF 44/145 reads (30%) | catalogued as COSV65788554; called by muse, mutect2, varscan2
- SLCO1B3 | c.595T>G p.F199V | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53942471; called by mutect2, varscan2
- SLCO2B1 | c.1812G>T p.M604I | Missense Mutation (SNP) | VAF 39/253 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as rs754635131, COSV56937415; called by muse, mutect2, varscan2
- SLITRK4 | c.526C>T p.R176* | Nonsense Mutation (SNP) | VAF 19/102 reads (19%) | catalogued as COSV62024561; called by muse, mutect2, varscan2
- SMC5 | c.3107T>G p.M1036R | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV63194417; called by muse, mutect2
- SMOC2 | c.85-2A>C p.X29_splice | Splice Site (SNP) | VAF 9/117 reads (8%) | catalogued as COSV62441298; called by muse, mutect2
- SMTN | c.242G>T p.R81L | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV60780919; called by muse, mutect2, varscan2
- SNIP1 | c.110A>T p.E37V | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.282); catalogued as rs1237079791, COSV56167592; called by muse, mutect2, varscan2
- SORBS3 | c.1831C>T p.Q611* | Nonsense Mutation (SNP) | VAF 7/58 reads (12%) | catalogued as COSV53554022; called by muse, mutect2, varscan2
- SORCS1 | c.2059-1G>A p.X687_splice | Splice Site (SNP) | VAF 47/148 reads (32%) | catalogued as COSV53850676, COSV53887355; called by muse, mutect2, varscan2
- SORCS3 | c.2267A>C p.Y756S | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63796906; called by muse, varscan2
- SORL1 | c.4973A>T p.Q1658L | Missense Mutation (SNP) | VAF 19/193 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.921); catalogued as COSV52758520; called by muse, mutect2, varscan2
- SPARC | c.595A>G p.I199V | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as COSV50559615; called by muse, mutect2, varscan2
- SPATA18 | c.1212G>T p.K404N | Missense Mutation (SNP) | VAF 37/354 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV54641818; called by muse, varscan2
- SPATA31D1 | c.2300A>G p.E767G | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV61198672; called by muse, mutect2, varscan2
- SPATC1 | c.719C>A p.T240N | Missense Mutation (SNP) | VAF 32/47 reads (68%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV66299463; called by muse, mutect2, varscan2
- SPEF2 | c.4807A>T p.N1603Y | Missense Mutation (SNP) | VAF 20/290 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV57430912; called by muse, mutect2
- SPRY1 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 31/234 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.243); catalogued as COSV59338861; called by muse, mutect2, varscan2
- SPTA1 | c.1240C>A p.Q414K | Missense Mutation (SNP) | VAF 22/261 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as COSV100934743, COSV63756879; called by muse, mutect2
- SRGAP1 | c.956T>C p.M319T | Missense Mutation (SNP) | VAF 66/132 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV61900907; called by muse, mutect2, varscan2
- SSC4D | c.1571G>C p.G524A | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV51883223; called by muse, mutect2
- SSMEM1 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 25/237 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV52834034; called by muse, mutect2, varscan2
- STK31 | c.767A>G p.K256R | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.251); catalogued as rs1232773425, COSV63458071; called by muse, mutect2
- SURF6 | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.95); PolyPhen benign (0.007); catalogued as rs782004715, COSV64395695; called by muse, mutect2, varscan2
- SUSD3 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.175); catalogued as rs202073425, COSV64937168; called by muse, mutect2, varscan2
- SYNE1 | c.10102G>T p.D3368Y (on ENST00000367255 / NM_182961.4; = p.D3375Y on NM_033071.3) | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV55042488; called by muse, mutect2, varscan2
- SYNE1 | c.986A>T p.Q329L (on ENST00000367255 / NM_182961.4; = p.Q336L on NM_033071.3) | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); catalogued as COSV55042540; called by muse, mutect2, varscan2
- TANGO2 | c.304A>T p.S102C | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.081); catalogued as COSV59294555; called by muse, mutect2
- TAS2R14 | c.66A>T p.L22F | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.58); catalogued as COSV101114285; called by muse, mutect2, varscan2
- TBX15 | c.1292C>A p.A431D (on ENST00000369429 / NM_001330677.2; = p.A325D on NM_152380.3) | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.076); catalogued as COSV52873904; called by muse, varscan2
- TEAD1 | c.249G>C p.K83N | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57567781; called by muse, mutect2, varscan2
- TENM1 | c.6947C>T p.A2316V | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.77); catalogued as COSV64438017; called by muse, mutect2, varscan2
- TENM2 | c.6096del p.Y2033Tfs*17 (on ENST00000518659 / NM_001122679.2; = p.Y1794Tfs*17 on NM_001080428.3) | Frame Shift Del (DEL) | VAF 24/99 reads (24%) | catalogued as COSV69127360; called by mutect2, pindel, varscan2
- TENT5A | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.338); catalogued as COSV100198785, COSV60787395; called by muse, mutect2, varscan2
- TFCP2 | c.854A>T p.Y285F | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.716); catalogued as COSV56934610; called by muse, mutect2, varscan2
- TGIF2LX | c.300del p.W100Cfs*87 | Frame Shift Del (DEL) | VAF 25/240 reads (10%) | catalogued as COSV52215586, COSV99383470; called by mutect2, varscan2
- TJP3 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs565934761, COSV53664328; called by muse, mutect2, varscan2
- TKFC | c.700G>T p.A234S | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.307); catalogued as COSV67523643, COSV67523889; called by muse, mutect2, varscan2
- TLR4 | c.2392G>T p.E798* (on ENST00000355622 / NM_138554.5; = p.E758* on NM_003266.4) | Nonsense Mutation (SNP) | VAF 28/181 reads (15%) | catalogued as COSV62923817, COSV62923972; called by muse, mutect2, varscan2
- TMC2 | c.1682G>T p.R561L | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT tolerated (0.82); PolyPhen benign (0.015); catalogued as rs745583676, COSV62654110, COSV62656109; called by muse, mutect2, varscan2
- TMC7 | c.2028-2A>T p.X676_splice | Splice Site (SNP) | VAF 33/171 reads (19%) | catalogued as COSV58585688; called by muse, mutect2, varscan2
- TMEM132E | c.2427C>A p.C809* (on ENST00000321639; = p.C899* on NM_001304438.2) | Nonsense Mutation (SNP) | VAF 19/113 reads (17%) | catalogued as COSV58699105; called by muse, mutect2, varscan2
- TMEM186 | c.631A>T p.M211L | Missense Mutation (SNP) | VAF 68/184 reads (37%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV99191110; called by muse, mutect2, varscan2
- TMEM200A | c.515C>A p.T172K | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.149); catalogued as COSV51656363; called by muse, mutect2
- TMEM39B | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.992); catalogued as COSV100297902; called by muse, mutect2, varscan2
- TMIGD1 | c.288C>G p.D96E | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61028949; called by muse, mutect2, varscan2
- TMTC1 | c.1636C>A p.Q546K (on ENST00000539277 / NM_001193451.2; = p.Q438K on NM_175861.3) | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV55488061; called by muse, mutect2, varscan2
- TNFRSF1B | c.425A>T p.K142M | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV66164750; called by muse, mutect2, varscan2
- TNS1 | c.1711C>T p.H571Y | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.077); catalogued as COSV50731368; called by muse, mutect2, varscan2
- TPD52 | c.187G>T p.A63S (on ENST00000379097 / NM_001025252.3; = p.A23S on NM_005079.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/577 reads (7%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.527); catalogued as COSV66951187; called by muse, mutect2
- TPK1 | c.545G>T p.W182L | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1252125179, COSV63644403; called by muse, mutect2, varscan2
- TRIM27 | c.801G>T p.W267C | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); catalogued as COSV65873836; called by muse, mutect2, varscan2
- TRMT12 | c.594G>T p.W198C | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60777548; called by muse, mutect2, varscan2
- TRO | c.1808A>G p.Y603C | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1311769589, COSV51504885; called by muse, mutect2, varscan2
- TSHZ3 | c.497A>G p.D166G | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99550829; called by muse, varscan2
- TTK | c.1811G>T p.C604F | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57885370; called by muse, mutect2, varscan2
- TTN | c.85742T>A p.L28581H (on ENST00000591111; = p.L21157H on NM_003319.4) | Missense Mutation (SNP) | VAF 16/196 reads (8%) | PolyPhen probably damaging (0.999); catalogued as COSV60206537; called by muse, mutect2
- TTN | c.55757G>T p.S18586I (on ENST00000591111; = p.S11162I on NM_003319.4) | Missense Mutation (SNP) | VAF 20/326 reads (6%) | PolyPhen benign (0.124); catalogued as COSV60206621; called by muse, mutect2
- TTN | c.39889G>T p.V13297L (on ENST00000591111; = p.V5873L on NM_003319.4) | Missense Mutation (SNP) | VAF 12/133 reads (9%) | PolyPhen benign (0.059); catalogued as COSV60206657; called by muse, mutect2
- TUFT1 | c.358A>G p.I120V | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as rs778944952, COSV61949696; called by muse, mutect2, varscan2
- UAP1 | c.19A>G p.K7E | Missense Mutation (SNP) | VAF 13/233 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV54852281; called by muse, mutect2
- UBA6 | c.2965G>C p.G989R | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV59179531; called by muse, mutect2, varscan2
- UBAP2 | c.2288A>G p.N763S | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV62547944; called by muse, mutect2
- UBE2A | c.242-2A>T p.X81_splice | Splice Site (SNP) | VAF 23/71 reads (32%) | catalogued as COSV100660484; called by muse, mutect2, varscan2
- UBE4B | c.2903C>T p.P968L (on ENST00000343090 / NM_001105562.3; = p.P839L on NM_006048.5) | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV53537244; called by muse, mutect2, varscan2
- USH2A | c.10240G>A p.G3414S | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV56403416; called by muse, mutect2
- USP17L2 | c.790T>A p.S264T | Missense Mutation (SNP) | VAF 12/155 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.173); catalogued as COSV61556123, COSV61556242; called by muse, mutect2
- USP51 | c.515G>T p.G172V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.037); catalogued as COSV72351819; called by muse, mutect2, varscan2
- VSTM4 | c.217G>T p.A73S | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.023); catalogued as COSV100039162; called by muse, mutect2, varscan2
- VWF | c.1726A>C p.M576L | Missense Mutation (SNP) | VAF 42/318 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV54628028; called by muse, mutect2, varscan2
- WDFY3 | c.7657G>T p.G2553W | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55708713; called by muse, mutect2, varscan2
- WDR13 | c.758G>T p.R253L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV99489153; called by muse, mutect2, varscan2
- WDR33 | c.1960G>C p.G654R | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.044); catalogued as COSV59253058; called by muse, mutect2, varscan2
- WNT3A | c.261C>G p.N87K | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1558286437, COSV52732540; called by muse, mutect2, varscan2
- XIRP2 | c.8130A>T p.K2710N (on ENST00000628543; = p.K2885N on NM_152381.6) | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV54718624; called by muse, mutect2, varscan2
- ZEB2 | c.2444C>A p.P815H | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100355226; called by muse, mutect2, varscan2
- ZEB2 | c.2443C>A p.P815T | Missense Mutation (SNP) | VAF 47/153 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100355233; called by muse, mutect2, varscan2
- ZFHX4 | c.5167C>A p.P1723T | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50512080, COSV51476340; called by muse, mutect2, varscan2
- ZFP30 | c.958C>T p.H320Y | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63622862; called by muse, mutect2, varscan2
- ZFPM2 | c.640C>T p.L214F | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.145); catalogued as COSV65874822; called by muse, mutect2, varscan2
- ZGRF1 | c.313C>T p.L105F | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as COSV52202135; called by muse, varscan2
- ZMIZ1 | c.1084G>T p.G362C | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV57900290; called by muse, mutect2, varscan2
- ZNF253 | c.200G>T p.R67I | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV63037967; called by muse, mutect2, varscan2
- ZNF257 | c.1583C>T p.S528L | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV71310221; called by muse, mutect2, varscan2
- ZNF333 | c.1718A>T p.E573V | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.915); catalogued as COSV99468873; called by muse, mutect2, varscan2
- ZNF611 | c.1591G>C p.G531R | Missense Mutation (SNP) | VAF 89/193 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV60542369; called by muse, mutect2, varscan2
- ZNF629 | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV52699679; called by muse, mutect2, varscan2
- ZNF652 | c.1354A>T p.S452C | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV62948018; called by muse, mutect2, varscan2
- ZNF747 | c.572G>C p.G191A | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.467); catalogued as COSV99411384; called by muse, varscan2
- ZSCAN1 | c.1081G>A p.V361I | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs369547013; called by muse, mutect2, varscan2
- ARPP21 | c.796del p.Q266Kfs*26 | Frame Shift Del (DEL) | VAF 5/51 reads (10%) | called by mutect2, pindel
- CBWD6 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- CCL3L3 | c.134A>C p.Q45P | Missense Mutation (SNP) | VAF 43/244 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- CRACD | c.3150dup p.E1051Rfs*114 | Frame Shift Ins (INS) | VAF 7/46 reads (15%) | called by mutect2, pindel, varscan2
- GOPC | c.569del p.R190Lfs*4 | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | called by mutect2, pindel*
- KCNA4 | c.872del p.K291Sfs*19 | Frame Shift Del (DEL) | VAF 8/65 reads (12%) | called by mutect2, varscan2
- LRP12 | c.729dup p.D244* | Frame Shift Ins (INS) | VAF 19/169 reads (11%) | called by mutect2, pindel, varscan2
- MRC1 | c.2344+1G>T p.X782_splice | Splice Site (SNP) | VAF 33/175 reads (19%) | called by muse, mutect2, varscan2
- NAV3 | c.4508del p.P1503Qfs*97 | Frame Shift Del (DEL) | VAF 20/93 reads (22%) | called by mutect2, pindel, varscan2
- NCOA4 | c.731G>T p.C244F | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NR1D1 | c.517del p.E173Rfs*52 | Frame Shift Del (DEL) | VAF 18/104 reads (17%) | called by mutect2, pindel, varscan2
- PLA2G4A | c.1836dup p.D613* | Frame Shift Ins (INS) | VAF 16/103 reads (16%) | called by mutect2, pindel, varscan2
- PPIAL4A | c.329C>A p.S110Y | Missense Mutation (SNP) | VAF 18/286 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SERAC1 | c.213del p.M71Ifs*12 | Frame Shift Del (DEL) | VAF 14/92 reads (15%) | called by mutect2, pindel, varscan2
- SPATA31A1 | c.2984C>A p.S995Y | Missense Mutation (SNP) | VAF 96/218 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- STYXL2 | c.1646del p.I549Tfs*28 | Frame Shift Del (DEL) | VAF 13/145 reads (9%) | called by mutect2, pindel
- SVOP | c.829dup p.T277Nfs*8 | Frame Shift Ins (INS) | VAF 52/281 reads (19%) | called by mutect2, pindel, varscan2
- TRBV4-2 | c.298C>A p.L100M | Missense Mutation (SNP) | VAF 62/703 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- VCAN | c.1830_1845del p.I610Mfs*17 | Frame Shift Del (DEL) | VAF 16/125 reads (13%) | called by mutect2, pindel
- ZFAT | c.126dup p.D43* | Frame Shift Ins (INS) | VAF 17/109 reads (16%) | called by mutect2, pindel, varscan2
- ZNF585A | c.1741A>T p.T581S (on ENST00000292841 / NM_001288800.2; = p.T526S on NM_152655.3) | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- AACS | c.1605C>T p.V535= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV55538972; called by muse, mutect2, varscan2
- ABCB11 | c.2889T>G p.L963= | Silent (SNP) | VAF 24/206 reads (12%) | catalogued as COSV55596063; called by muse, mutect2, varscan2
- ACTRT2 | c.78T>A p.S26= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV65759903; called by muse, mutect2, varscan2
- ADGRA1 | c.429C>T p.P143= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV66926570; called by muse, mutect2, varscan2
- ADGRF5 | c.3429G>T p.S1143= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs142588297, COSV51937422; called by muse, mutect2, varscan2
- AFDN | c.4200G>T p.P1400= | Silent (SNP) | VAF 38/159 reads (24%) | catalogued as COSV60050343; called by muse, mutect2, varscan2
- AKAP4 | c.1731T>C p.Y577= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as COSV62074963; called by muse, mutect2, varscan2
- AKR1D1 | c.294C>A p.V98= | Silent (SNP) | VAF 38/124 reads (31%) | catalogued as rs113371817, COSV54339022; called by muse, mutect2, varscan2
- ALG9 | c.1653T>C p.Y551= (on ENST00000614444 / NM_001352418.1; = p.Y558= on NM_024740.2) | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV67645018; called by muse, mutect2, varscan2
- ANPEP | c.441C>A p.P147= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as COSV55593249; called by muse, mutect2, varscan2
- ASB15 | c.732G>T p.A244= | Silent (SNP) | VAF 57/202 reads (28%) | catalogued as COSV51925742, COSV51927855; called by muse, mutect2, varscan2
- BSN | c.7968C>T p.A2656= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV56523426, COSV99610032; called by muse, mutect2, varscan2
- CACNA1G | c.727C>T p.L243= | Silent (SNP) | VAF 5/78 reads (6%) | catalogued as COSV61732820; called by muse, mutect2
- CCT8L2 | c.330G>A p.L110= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV63463238; called by muse, mutect2, varscan2
- CDH10 | c.2007C>A p.A669= | Silent (SNP) | VAF 69/115 reads (60%) | catalogued as COSV52589315; called by muse, mutect2, varscan2
- CDH22 | c.1614G>A p.L538= | Silent (SNP) | VAF 9/121 reads (7%) | catalogued as COSV64838723; called by muse, mutect2
- CEL | c.468C>T p.R156= (on ENST00000673714; = p.R153= on NM_001807.6) | Silent (SNP) | VAF 68/396 reads (17%) | catalogued as rs368097381; called by muse, mutect2, varscan2
- CHGB | c.396G>A p.E132= | Silent (SNP) | VAF 6/9 reads (67%) | catalogued as rs1306412217, COSV66761259; called by muse, mutect2, varscan2
- CLEC4F | c.1206C>T p.A402= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as rs782544606, COSV55480492; called by muse, mutect2
- CLN3 | c.315C>T p.L105= (on ENST00000360019 / NM_001286104.2; = p.L129= on NM_000086.2) | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as rs765776873, COSV61106452; called by muse, mutect2, varscan2
- CNTD1 | c.780T>A p.I260= | Silent (SNP) | VAF 23/120 reads (19%) | catalogued as COSV59312409; called by muse, mutect2, varscan2
- CNTN6 | c.3027C>A p.T1009= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV63181385; called by muse, mutect2, varscan2
- COL13A1 | c.1218C>A p.G406= (on ENST00000398978 / NM_001130103.2; = p.G349= on NM_080798.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV100637329; called by muse, mutect2, varscan2
- COL14A1 | c.981G>T p.V327= | Silent (SNP) | VAF 30/87 reads (34%) | catalogued as COSV52861947; called by muse, mutect2, varscan2
- COL26A1 | c.318C>G p.S106= (on ENST00000313669 / NM_001278563.3; = p.S104= on NM_133457.4) | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV58128590; called by muse, mutect2, varscan2
- CPNE4 | c.411A>C p.T137= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as COSV70197373; called by muse, mutect2, varscan2
- CSPG4 | c.6858C>A p.L2286= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV57898851; called by muse, varscan2
- CYP11B2 | c.1002C>A p.P334= | Silent (SNP) | VAF 57/115 reads (50%) | catalogued as rs140463031, COSV59997002; called by muse, mutect2, varscan2
- CYP11B2 | c.909C>A p.A303= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as COSV100010756; called by muse, mutect2, varscan2
- CYP2U1 | c.1107G>T p.S369= | Silent (SNP) | VAF 22/199 reads (11%) | catalogued as COSV60549377; called by muse, mutect2, varscan2
- DCBLD1 | c.1392G>T p.V464= | Silent (SNP) | VAF 43/362 reads (12%) | catalogued as COSV51641353, COSV51643761; called by muse, mutect2, varscan2
- DDX18 | c.465T>C p.D155= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV54308110; called by muse, mutect2, varscan2
- DGKI | c.3022C>A p.R1008= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as COSV55964018; called by muse, mutect2, varscan2
- DNAH11 | c.6747G>A p.K2249= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV60967931; called by mutect2, varscan2
- DNAH7 | c.3072C>T p.V1024= | Silent (SNP) | VAF 10/146 reads (7%) | catalogued as COSV56775565; called by muse, mutect2
- DNAH9 | c.1188G>T p.V396= | Silent (SNP) | VAF 12/185 reads (6%) | catalogued as COSV99304550; called by muse, mutect2
- DNAJC5B | c.273C>A p.A91= | Silent (SNP) | VAF 40/188 reads (21%) | catalogued as rs1468376532, COSV99395479; called by muse, mutect2, varscan2
- EIF5B | c.1257C>A p.A419= | Silent (SNP) | VAF 13/176 reads (7%) | catalogued as COSV56814718, COSV56815418; called by muse, mutect2
- EME2 | c.1032G>T p.P344= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as COSV99456685; called by muse, mutect2, varscan2
- EPGN | c.381T>A p.V127= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as COSV100141374; called by muse, mutect2, varscan2
- EPHA3 | c.2472A>T p.P824= | Silent (SNP) | VAF 27/219 reads (12%) | catalogued as COSV60716721; called by muse, mutect2, varscan2
- EPHB1 | c.879C>T p.S293= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV101212768; called by muse, mutect2, varscan2
- FAM47C | c.1068G>A p.P356= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as rs782389624, COSV63728861; called by muse, mutect2, varscan2
- FBN3 | c.2104C>A p.R702= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV54466990; called by muse, mutect2, varscan2
- FCN1 | c.828A>T p.G276= | Silent (SNP) | VAF 24/211 reads (11%) | catalogued as COSV65662702; called by muse, mutect2, varscan2
- FLG | c.4380C>A p.P1460= | Silent (SNP) | VAF 58/462 reads (13%) | catalogued as COSV64245072; called by muse, mutect2, varscan2
- FPR3 | c.945C>A p.R315= | Silent (SNP) | VAF 48/124 reads (39%) | catalogued as COSV59331040; called by muse, mutect2, varscan2
- FREM1 | c.3750A>T p.T1250= | Silent (SNP) | VAF 55/106 reads (52%) | catalogued as COSV66527008; called by muse, mutect2, varscan2
- FRY | c.7764T>A p.I2588= | Silent (SNP) | VAF 27/109 reads (25%) | catalogued as rs764151494, COSV66574841; called by muse, mutect2, varscan2
- GADL1 | c.618T>G p.G206= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV56982481; called by muse, mutect2, varscan2
- GCNT1 | c.738G>A p.R246= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as rs774153143, COSV65058264; called by muse, mutect2, varscan2
- GFI1 | c.1152C>T p.I384= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV54043311; called by muse, mutect2, varscan2
- GHR | c.1146C>A p.G382= | Silent (SNP) | VAF 18/165 reads (11%) | catalogued as COSV50109690, COSV50121383; called by muse, mutect2, varscan2
- GOLGA2 | c.2430G>C p.L810= | Silent (SNP) | VAF 56/628 reads (9%) | catalogued as COSV57854275; called by muse, mutect2
- GOLM2 | c.189G>A p.L63= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV55465070; called by muse, mutect2, varscan2
- GORASP2 | c.1062C>T p.G354= | Silent (SNP) | VAF 13/184 reads (7%) | catalogued as COSV52203009; called by muse, mutect2
- GPR17 | c.423C>T p.L141= | Silent (SNP) | VAF 8/154 reads (5%) | catalogued as COSV55756366; called by muse, mutect2
- GPR45 | c.771G>T p.V257= | Silent (SNP) | VAF 27/215 reads (13%) | catalogued as COSV51525366; called by muse, mutect2, varscan2
- GRIK3 | c.1032C>A p.T344= | Silent (SNP) | VAF 18/175 reads (10%) | catalogued as COSV66139224; called by muse, mutect2, varscan2
- GRM8 | c.1725C>A p.I575= | Silent (SNP) | VAF 19/115 reads (17%) | catalogued as COSV58848055, COSV58874063; called by muse, mutect2, varscan2
- GSK3B | c.249C>T p.A83= | Silent (SNP) | VAF 48/235 reads (20%) | catalogued as rs141817453, COSV51779641; called by muse, mutect2, varscan2
- HEPH | c.870G>T p.V290= (on ENST00000343002; = p.V23= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/143 reads (26%) | catalogued as COSV57968160; called by muse, mutect2, varscan2
- HTR1F | c.33G>A p.L11= | Silent (SNP) | VAF 19/155 reads (12%) | catalogued as COSV60389782; called by muse, mutect2, varscan2
- HVCN1 | c.714G>A p.L238= | Silent (SNP) | VAF 51/105 reads (49%) | catalogued as COSV54373376; called by muse, mutect2, varscan2
- IGFL4 | c.231G>A p.L77= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as COSV66618972; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.252G>A p.Q84= | Silent (SNP) | VAF 51/284 reads (18%) | catalogued as rs772237521; called by muse, mutect2, varscan2
- IGSF21 | c.750G>T p.L250= | Silent (SNP) | VAF 38/181 reads (21%) | catalogued as COSV52139168; called by muse, mutect2, varscan2
- IQGAP2 | c.612C>G p.A204= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV57177576; called by muse, mutect2
- ISY1-RAB43 | c.774G>A p.R258= | Silent (SNP) | VAF 16/138 reads (12%) | catalogued as rs1466168863, COSV56442141; called by muse, mutect2, varscan2
- ITGAX | c.1587G>T p.G529= | Silent (SNP) | VAF 71/301 reads (24%) | catalogued as rs759429758, COSV51643763; called by muse, mutect2, varscan2
- ITSN2 | c.414A>T p.T138= | Silent (SNP) | VAF 8/79 reads (10%) | catalogued as COSV61951092; called by muse, mutect2, varscan2
- JPH4 | c.1698C>A p.P566= | Silent (SNP) | VAF 22/102 reads (22%) | catalogued as COSV58114282; called by muse, mutect2
- KCNV1 | c.924G>T p.G308= | Silent (SNP) | VAF 48/81 reads (59%) | catalogued as COSV52087598; called by muse, mutect2, varscan2
- KIDINS220 | c.1554C>T p.F518= | Silent (SNP) | VAF 12/152 reads (8%) | catalogued as COSV56756689; called by muse, mutect2
- KIF20B | c.4896A>T p.P1632= (on ENST00000371728 / NM_001284259.2; = p.P1592= on NM_016195.4) | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV53311666; called by muse, mutect2, varscan2
- KIR3DL1 | c.1239C>A p.R413= | Silent (SNP) | VAF 80/309 reads (26%) | catalogued as COSV58493714; called by muse, mutect2, varscan2
- KLHL23 | c.888A>T p.T296= | Silent (SNP) | VAF 103/327 reads (31%) | catalogued as COSV99775587; called by muse, mutect2, varscan2
- KPRP | c.1188G>A p.L396= | Silent (SNP) | VAF 27/111 reads (24%) | catalogued as COSV64222376; called by muse, mutect2, varscan2
- KRT39 | c.825C>A p.I275= | Silent (SNP) | VAF 150/703 reads (21%) | catalogued as COSV62917281, COSV62917705; called by muse, mutect2, varscan2
- LARP6 | c.1053G>A p.A351= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as rs148356697; called by muse, mutect2, varscan2
- LAYN | c.525G>T p.R175= (on ENST00000375615 / NM_001258390.1; = p.R167= on NM_178834.5) | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV100986172; called by muse, mutect2, varscan2
- LRP1B | c.3277C>A p.R1093= | Silent (SNP) | VAF 64/232 reads (28%) | catalogued as rs760133840, COSV67250967; called by muse, mutect2, varscan2
- LRP1B | c.1953G>T p.V651= | Silent (SNP) | VAF 34/109 reads (31%) | catalogued as COSV67250970; called by muse, mutect2, varscan2
- LRRC4C | c.1164T>C p.T388= | Silent (SNP) | VAF 43/177 reads (24%) | catalogued as COSV53432453; called by muse, mutect2, varscan2
- LRTM1 | c.267G>T p.L89= | Silent (SNP) | VAF 6/63 reads (10%) | catalogued as COSV55561851, COSV99835882; called by muse, mutect2, varscan2
- MC2R | c.141G>A p.L47= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV100562880, COSV100562912; called by muse, mutect2, varscan2
- MGA | c.6783A>G p.A2261= (on ENST00000219905 / NM_001164273.1; = p.A2052= on NM_001080541.2) | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV54959127; called by muse, mutect2, varscan2
- MIDEAS | c.537G>T p.V179= | Silent (SNP) | VAF 19/123 reads (15%) | catalogued as COSV54096973; called by muse, mutect2, varscan2
- MLIP | c.792C>G p.L264= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV51433789; called by muse, mutect2, varscan2
- MS4A7 | c.159C>A p.I53= | Silent (SNP) | VAF 44/211 reads (21%) | catalogued as COSV55730147; called by muse, mutect2, varscan2
- MUC16 | c.32733C>A p.T10911= | Silent (SNP) | VAF 22/116 reads (19%) | catalogued as COSV101198481; called by muse, mutect2, varscan2
- MUC17 | c.6408T>A p.S2136= | Silent (SNP) | VAF 137/610 reads (22%) | catalogued as COSV60296529; called by muse, mutect2, varscan2
- MXRA5 | c.396G>T p.L132= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV54242999; called by muse, mutect2, varscan2
- MYH2 | c.1860A>T p.L620= | Silent (SNP) | VAF 61/255 reads (24%) | catalogued as COSV55443528; called by muse, mutect2, varscan2
- MYH9 | c.3339C>A p.I1113= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV53390322; called by muse, mutect2, varscan2
- MYO5A | c.3438G>A p.K1146= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as COSV62562655; called by muse, mutect2, varscan2
- MYT1 | c.165C>A p.P55= | Silent (SNP) | VAF 30/105 reads (29%) | catalogued as COSV60509376, COSV60510084; called by muse, mutect2, varscan2
- NEB | c.14403C>A p.A4801= | Silent (SNP) | VAF 57/215 reads (27%) | catalogued as COSV51438805; called by muse, mutect2, varscan2
- NELL1 | c.2149C>A p.R717= | Silent (SNP) | VAF 29/112 reads (26%) | catalogued as COSV100120660, COSV54296011; called by muse, mutect2, varscan2
- NINL | c.909G>C p.V303= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV54006096; called by muse, mutect2, varscan2
- NLGN4X | c.1362G>C p.V454= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV52028143; called by muse, mutect2, varscan2
- NLRP12 | c.18C>G p.G6= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV60751022; called by muse, mutect2, varscan2
- NLRP14 | c.366T>C p.D122= | Silent (SNP) | VAF 41/91 reads (45%) | catalogued as COSV55069890; called by muse, mutect2, varscan2
- NTF3 | c.208C>A p.R70= | Silent (SNP) | VAF 16/131 reads (12%) | catalogued as COSV58418001; called by muse, mutect2, varscan2
- OLFML2B | c.1755C>A p.I585= | Silent (SNP) | VAF 16/120 reads (13%) | catalogued as COSV54198592, COSV99668369; called by muse, mutect2, varscan2
- OR3A1 | c.264C>A p.L88= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV100041575, COSV100041798; called by muse, mutect2, varscan2
- OR4D11 | c.378C>T p.I126= | Silent (SNP) | VAF 50/258 reads (19%) | catalogued as rs761267797, COSV57586468; called by muse, mutect2, varscan2
- OR51B2 | c.129C>A p.L43= | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as COSV60917226; called by muse, mutect2, varscan2
- OR5B3 | c.30C>T p.F10= | Silent (SNP) | VAF 20/160 reads (13%) | catalogued as rs767629637, COSV100511923; called by muse, mutect2, varscan2
- OR5K2 | c.624C>A p.V208= | Silent (SNP) | VAF 30/190 reads (16%) | catalogued as COSV71143051, COSV71143345; called by muse, mutect2, varscan2
- OR5M11 | c.234C>A p.T78= | Silent (SNP) | VAF 20/117 reads (17%) | catalogued as COSV73141946; called by muse, mutect2, varscan2
- OVCH1 | c.375T>A p.I125= | Silent (SNP) | VAF 96/160 reads (60%) | catalogued as COSV58965909; called by muse, mutect2, varscan2
- PADI4 | c.712C>T p.L238= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as rs1163641528, COSV64924530; called by muse, mutect2
- PARP10 | c.2365C>T p.L789= | Silent (SNP) | VAF 4/59 reads (7%) | catalogued as COSV57299145; called by muse, mutect2
- PARP16 | c.405C>T p.N135= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as rs891750608, COSV56036083; called by muse, mutect2, varscan2
- PASK | c.2052G>T p.P684= | Silent (SNP) | VAF 32/291 reads (11%) | catalogued as COSV52156727; called by muse, mutect2, varscan2
- PCDH17 | c.426G>T p.S142= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV64976722, COSV64977781; called by muse, mutect2, varscan2
- PCED1B | c.547C>A p.R183= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as COSV71395344; called by muse, mutect2, varscan2
- PIK3AP1 | c.375C>T p.T125= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as rs530974413, COSV59534749; called by muse, mutect2, varscan2
- PLCB1 | c.552A>T p.R184= | Silent (SNP) | VAF 5/84 reads (6%) | catalogued as COSV62060247, COSV62061859; called by muse, mutect2
- PLCE1 | c.1185G>T p.L395= | Silent (SNP) | VAF 21/80 reads (26%) | catalogued as rs762259865, COSV53361825; called by muse, mutect2, varscan2
- PLEKHM3 | c.1792C>T p.L598= | Silent (SNP) | VAF 46/162 reads (28%) | catalogued as COSV66817703; called by muse, mutect2, varscan2
- POF1B | c.1015C>A p.R339= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV53130401, COSV53137512; called by muse, mutect2, varscan2
- PPP2R1A | c.1725C>T p.V575= | Silent (SNP) | VAF 14/139 reads (10%) | catalogued as COSV59046545; called by muse, mutect2, varscan2
- PPP2R2C | c.696G>A p.P232= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as rs767816512, COSV58674447; called by muse, mutect2, varscan2
- PRICKLE3 | c.537G>A p.V179= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV66235180; called by muse, mutect2, varscan2
- PTPRN2 | c.2295C>T p.A765= | Silent (SNP) | VAF 80/554 reads (14%) | catalogued as COSV67051234; called by muse, mutect2, varscan2
- PTPRN2 | c.519C>G p.T173= | Silent (SNP) | VAF 30/85 reads (35%) | catalogued as COSV67051249; called by muse, mutect2, varscan2
- RADIL | c.120C>T p.D40= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV68202478; called by muse, mutect2, varscan2
- RBFOX2 | c.552G>C p.L184= (on ENST00000438146 / NM_001349995.2; = p.L114= on NM_014309.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 69/282 reads (24%) | catalogued as COSV53266816; called by muse, mutect2, varscan2
- REV1 | c.1290A>T p.S430= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as COSV51487216; called by muse, mutect2, varscan2
- RP1L1 | c.732G>T p.L244= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV100261709; called by muse, mutect2, varscan2
- SALL1 | c.1968C>A p.T656= | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as COSV51761295; called by muse, mutect2, varscan2
- SALL1 | c.1641C>A p.V547= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as COSV51761303; called by muse, mutect2, varscan2
- SCYL1 | c.1752G>C p.L584= | Silent (SNP) | VAF 10/190 reads (5%) | catalogued as COSV54214198; called by muse, mutect2
- SHOC2 | c.981A>G p.L327= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as rs1440014484, COSV54622994; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC28A3 | c.792G>A p.L264= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV66154222; called by muse, mutect2, varscan2
- SLC39A12 | c.2001G>T p.L667= (on ENST00000377369 / NM_001145195.2; = p.L630= on NM_152725.3) | Silent (SNP) | VAF 25/89 reads (28%) | catalogued as COSV66200707; called by muse, mutect2, varscan2
- SLC39A6 | c.183C>T p.F61= | Silent (SNP) | VAF 41/141 reads (29%) | catalogued as COSV52370304; called by muse, mutect2, varscan2
- SMOC2 | c.681C>A p.A227= (on ENST00000356284 / NM_001166412.2; = p.A238= on NM_022138.3) | Silent (SNP) | VAF 23/135 reads (17%) | catalogued as rs752990585, COSV100634886; called by muse, mutect2, varscan2
- SORCS3 | c.2301C>T p.V767= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs755944785, COSV63796912; called by muse, varscan2
- SPAG1 | c.225G>A p.L75= | Silent (SNP) | VAF 12/119 reads (10%) | catalogued as COSV52561521; called by muse, mutect2, varscan2
- SPDYC | c.624C>A p.G208= | Silent (SNP) | VAF 27/87 reads (31%) | catalogued as rs756491320, COSV65865492; called by muse, mutect2, varscan2
- SPEM2 | c.831C>A p.A277= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV61604336; called by muse, mutect2, varscan2
- SRSF4 | c.603C>A p.S201= | Silent (SNP) | VAF 25/214 reads (12%) | catalogued as COSV65694582, COSV65695345; called by muse, mutect2, varscan2
- ST8SIA6 | c.471A>G p.E157= | Silent (SNP) | VAF 7/79 reads (9%) | catalogued as COSV66470144; called by muse, mutect2
- STAB2 | c.5259C>T p.Y1753= | Silent (SNP) | VAF 32/99 reads (32%) | catalogued as COSV66343287; called by muse, mutect2, varscan2
- SYNE1 | c.18564C>T p.L6188= (on ENST00000367255 / NM_182961.4; = p.L6117= on NM_033071.3) | Silent (SNP) | VAF 22/265 reads (8%) | catalogued as COSV55042450, COSV55105567; called by muse, mutect2
- TBC1D31 | c.1542C>T p.I514= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as COSV54866844; called by muse, mutect2, varscan2
- TFEB | c.387C>T p.H129= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as rs756151147, COSV100026006; called by muse, mutect2, varscan2
- TGM4 | c.705G>T p.G235= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV56095290; called by muse, mutect2, varscan2
- THUMPD2 | c.783G>T p.V261= | Silent (SNP) | VAF 56/142 reads (39%) | catalogued as COSV53188370; called by muse, mutect2, varscan2
- TLCD5 | c.645A>C p.A215= (on ENST00000375095 / NM_001198671.2; = p.A118= on NM_174926.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV100080943; called by muse, mutect2, varscan2
- TLR2 | c.637C>T p.L213= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as COSV52607373; called by muse, mutect2, varscan2
- TLR7 | c.480C>T p.I160= | Silent (SNP) | VAF 23/93 reads (25%) | catalogued as COSV66124894; called by muse, mutect2, varscan2
- TMEM117 | c.540C>A p.P180= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as COSV56912130; called by muse, mutect2, varscan2
- TMEM132D | c.159C>T p.I53= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as COSV70614872; called by muse, mutect2, varscan2
- TMEM69 | c.642G>A p.L214= | Silent (SNP) | VAF 10/132 reads (8%) | catalogued as rs1290869976, COSV63433173, COSV63433235; called by muse, mutect2
- TPSD1 | c.703C>T p.L235= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as COSV52977369, COSV99273842; called by muse, mutect2, varscan2
- TRBV4-2 | c.297C>A p.T99= | Silent (SNP) | VAF 62/708 reads (9%) | catalogued as rs1312844937; called by muse, mutect2
- TRBV5-1 | c.174A>G p.P58= | Silent (SNP) | VAF 8/53 reads (15%) | called by muse, mutect2, varscan2
- TRIM56 | c.1434G>C p.L478= | Silent (SNP) | VAF 93/362 reads (26%) | catalogued as COSV100047039; called by muse, mutect2, varscan2
- TRPM1 | c.2784G>T p.R928= | Silent (SNP) | VAF 38/104 reads (37%) | catalogued as COSV56638474; called by muse, mutect2, varscan2
- TRPM6 | c.4656G>A p.K1552= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV62517110; called by muse, varscan2
- TSGA13 | c.192T>C p.P64= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV63018994; called by muse, mutect2, varscan2
- TSHZ3 | c.2127C>A p.I709= | Silent (SNP) | VAF 12/103 reads (12%) | catalogued as COSV53677276; called by muse, mutect2, varscan2
- TTN | c.67425T>C p.N22475= (on ENST00000591111; = p.N15051= on NM_003319.4) | Silent (SNP) | VAF 10/143 reads (7%) | catalogued as rs1479696704, COSV60206580; called by muse, mutect2
- TUBGCP2 | c.1101A>C p.T367= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV53307204; called by muse, mutect2, varscan2
- UBQLN3 | c.504G>T p.V168= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as rs768737500, COSV100293410; called by muse, mutect2, varscan2
- UGT1A4 | c.60C>T p.L20= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as rs1458858352, COSV59394080; called by muse, mutect2, varscan2
- UNC5B | c.1134G>T p.A378= | Silent (SNP) | VAF 48/351 reads (14%) | catalogued as COSV58979083; called by muse, mutect2, varscan2
- USH2A | c.3628C>T p.L1210= | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as COSV56385473, COSV56403434; called by muse, mutect2, varscan2
- WDFY3 | c.5217G>T p.G1739= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV55708724; called by muse, mutect2, varscan2
- WEE2 | c.1209G>A p.E403= | Silent (SNP) | VAF 16/216 reads (7%) | catalogued as COSV101187652, COSV66879632; called by muse, mutect2
- ZNF100 | c.1212A>G p.E404= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV99973799; called by muse, mutect2
- ZNF536 | c.1467G>T p.L489= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as COSV100834516, COSV62829416; called by muse, mutect2, varscan2
- ZNF831 | c.3309G>T p.L1103= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV64043003; called by muse, mutect2, varscan2
- ZSWIM2 | c.810C>T p.H270= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV54577392; called by mutect2, varscan2
- AGAP7P | n.1184C>A | RNA (SNP) | VAF 19/309 reads (6%) | called by muse, mutect2
- AMER1 | c.*3706A>G | 3'UTR (SNP) | VAF 34/108 reads (31%) | catalogued as COSV100365519; called by muse, mutect2, varscan2
- C3orf35 | chr3:37417406 G>T | 3'Flank (SNP) | VAF 31/148 reads (21%) | called by muse, mutect2, varscan2
- CXCL12 | c.267-2646A>G | Intron (SNP) | VAF 20/186 reads (11%) | catalogued as COSV100638880; called by muse, mutect2, varscan2
- FAM27E5 | n.385G>T | RNA (SNP) | VAF 13/66 reads (20%) | catalogued as rs369352933; called by muse, varscan2
11 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 11 other) are not listed here.
